Somatic mutation profile of tumor specimen C3L-02627-04 (aliquot CPT0202020011) from CPTAC case C3L-02627, project CPTAC-3 (Bronchus and lung — Squamous Cell Neoplasms). Sex at birth: female; Vital status: Alive; Primary diagnosis: Squamous cell carcinoma, NOS; Tissue or organ of origin: Lung, NOS; AJCC pathologic stage: Stage IA; Tumor grade: G3; Age at diagnosis: 64.8 years (23,667 days).
Specimen C3L-02627-04: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Biospecimen anatomic site: Lung; Preservation method: Snap Frozen.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 1c886038-6e1e-4aee-b0b6-18eaad768701.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen C3L-02627-31 (Blood Derived Normal), aliquot CPT0202150002; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/e6a01798-53b2-4865-9a20-2436cfac46fe

The open-access MAF lists 676 somatic variants for this specimen: 463 protein-altering or splice-affecting, 128 silent, 85 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 391, Silent 128, Intron 37, Nonsense Mutation 37, RNA 19, Splice Site 13, Frame Shift Del 8, 3'Flank 8, 5'Flank 7, 5'UTR 7, 3'UTR 7, Splice Region 7.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- HNRNPK | c.248G>A p.G83D | Missense Mutation (SNP) | VAF 83/390 reads (21%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.969); catalogued as rs1064794967; ClinVar: likely pathogenic; called by muse, mutect2, varscan2
- TP53 | c.820G>T p.V274F | Missense Mutation (SNP) | VAF 227/620 reads (37%) | hotspot (GDC flag); SIFT deleterious (0.03); PolyPhen possibly damaging (0.496); catalogued as rs1057520005, COSV52707923, COSV52708386, COSV52728497, COSV53727597; ClinVar: likely pathogenic; called by muse, mutect2, varscan2
- A1CF | c.652C>A p.P218T | Missense Mutation (SNP) | VAF 7/20 reads (35%) | SIFT deleterious (0); PolyPhen possibly damaging (0.907); catalogued as COSV50957774; called by muse, mutect2
- AARS2 | c.1009G>T p.D337Y | Missense Mutation (SNP) | VAF 53/356 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (0.964); catalogued as COSV55117545; called by muse, mutect2, varscan2
- ABCB5 | c.3586C>G p.H1196D (on ENST00000404938 / NM_001163941.2; = p.H751D on NM_178559.6) | Missense Mutation (SNP) | VAF 37/149 reads (25%) | SIFT tolerated (0.31); PolyPhen benign (0); catalogued as COSV51705859; called by muse, mutect2, varscan2
- ABCC9 | c.1987C>G p.R663G | Missense Mutation (SNP) | VAF 78/384 reads (20%) | SIFT tolerated (0.43); PolyPhen benign (0.018); catalogued as CM141606; called by muse, mutect2, varscan2
- ACTR5 | c.936del p.R313Gfs*22 | Frame Shift Del (DEL) | VAF 42/204 reads (21%) | catalogued as COSV54760665; called by mutect2, pindel, varscan2
- ADAM2 | c.2180C>A p.P727H | Missense Mutation (SNP) | VAF 32/161 reads (20%) | SIFT tolerated (0.41); PolyPhen benign (0.094); catalogued as COSV55860348; called by muse, mutect2, varscan2
- ADAM8 | c.1444C>T p.R482W | Missense Mutation (SNP) | VAF 128/358 reads (36%) | SIFT deleterious (0.05); PolyPhen probably damaging (0.921); catalogued as rs147308914; called by muse, mutect2, varscan2
- ADAMTS12 | c.1503C>A p.C501* | Nonsense Mutation (SNP) | VAF 77/467 reads (16%) | catalogued as COSV61256645; called by muse, mutect2, varscan2
- ADAMTS7 | c.188G>A p.W63* | Nonsense Mutation (SNP) | VAF 208/973 reads (21%) | catalogued as rs753691849; called by muse, mutect2, varscan2
- ADAMTS9 | c.2926G>T p.D976Y | Missense Mutation (SNP) | VAF 157/464 reads (34%) | SIFT deleterious (0); PolyPhen possibly damaging (0.594); catalogued as COSV99898952; called by muse, mutect2, varscan2
- ADCY5 | c.1201G>T p.E401* | Nonsense Mutation (SNP) | VAF 78/445 reads (18%) | catalogued as rs1553733614, COSV59197885; called by muse, mutect2, varscan2
- ADCY8 | c.1225C>T p.R409C | Missense Mutation (SNP) | VAF 62/208 reads (30%) | SIFT deleterious (0); PolyPhen possibly damaging (0.803); catalogued as rs1335694203, COSV53903757, COSV99654082; called by muse, mutect2, varscan2
- AGBL1 | c.2185G>A p.A729T | Missense Mutation (SNP) | VAF 40/165 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (0.955); catalogued as COSV66856480; called by muse, mutect2, varscan2
- AHRR | c.1505C>G p.T502R | Missense Mutation (SNP) | VAF 13/91 reads (14%) | SIFT tolerated (0.08); PolyPhen benign (0.042); catalogued as COSV57082613; called by muse, mutect2, varscan2
- ALB | c.833C>A p.A278D | Missense Mutation (SNP) | VAF 190/503 reads (38%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.893); catalogued as COSV55743320; called by muse, mutect2, varscan2
- ALG13 | c.1392C>G p.I464M | Missense Mutation (SNP) | VAF 72/242 reads (30%) | SIFT deleterious (0.05); PolyPhen probably damaging (0.997); catalogued as COSV52644335; called by muse, varscan2
- ALOX5 | c.296C>T p.P99L | Missense Mutation (SNP) | VAF 118/503 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV65552131; called by muse, mutect2, varscan2
- ANO4 | c.2584C>A p.R862S (on ENST00000392977 / NM_001286615.2; = p.R827S on NM_178826.4) | Missense Mutation (SNP) | VAF 103/340 reads (30%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV54595545; called by muse, mutect2, varscan2
- ANPEP | c.500A>T p.K167M | Missense Mutation (SNP) | VAF 39/136 reads (29%) | SIFT tolerated (0.11); PolyPhen benign (0.039); catalogued as COSV55589310; called by muse, mutect2, varscan2
- AP002512.3 | c.1037C>A p.S346Y | Missense Mutation (SNP) | VAF 55/188 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (0.945); catalogued as COSV54409197; called by muse, mutect2, varscan2
- ARHGAP30 | c.2629G>A p.E877K | Missense Mutation (SNP) | VAF 126/502 reads (25%) | SIFT deleterious, low confidence (0.02); PolyPhen benign (0.146); catalogued as COSV63519180; called by muse, mutect2, varscan2
- ATP8B4 | c.1077G>T p.W359C | Missense Mutation (SNP) | VAF 90/416 reads (22%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.766); catalogued as COSV99465569; called by muse, mutect2, varscan2
- C1orf94 | c.1072C>T p.P358S (on ENST00000488417 / NM_001134734.2; = p.P168S on NM_032884.5) | Missense Mutation (SNP) | VAF 180/649 reads (28%) | SIFT tolerated, low confidence (0.17); PolyPhen benign (0.005); catalogued as COSV100975191, COSV64914504; called by muse, mutect2, varscan2
- CAMKK2 | c.629G>A p.R210H | Missense Mutation (SNP) | VAF 19/110 reads (17%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.994); catalogued as rs773178395; called by muse, mutect2, varscan2
- CD48 | c.369C>G p.I123M | Missense Mutation (SNP) | VAF 161/573 reads (28%) | SIFT deleterious (0); PolyPhen probably damaging (0.95); catalogued as COSV63566017; called by muse, mutect2, varscan2
- CD5L | c.920G>T p.R307L | Missense Mutation (SNP) | VAF 127/540 reads (24%) | SIFT tolerated (0.07); PolyPhen benign (0.049); catalogued as COSV100941049; called by muse, mutect2, varscan2
- CEBPE | c.817C>T p.L273F | Missense Mutation (SNP) | VAF 96/369 reads (26%) | SIFT tolerated (0.1); PolyPhen possibly damaging (0.737); catalogued as COSV52829793; called by muse, mutect2, varscan2
- CHEK2 | c.563G>T p.R188L (on ENST00000382580 / NM_001005735.2; = p.R145L on NM_007194.4) | Missense Mutation (SNP) | VAF 102/405 reads (25%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.783); catalogued as CM030415, CM092017, COSV60421027, COSV60424422; called by muse, mutect2, varscan2
- CLEC4M | c.1090G>A p.G364R | Missense Mutation (SNP) | VAF 49/218 reads (22%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.736); catalogued as rs141012314, COSV50220143; called by muse, mutect2, varscan2
- CLIP1 | c.2670G>T p.M890I (on ENST00000620786 / NM_001247997.1; = p.M879I on NM_002956.2) | Missense Mutation (SNP) | VAF 23/112 reads (21%) | SIFT tolerated (0.37); PolyPhen benign (0); catalogued as rs1219640118; called by muse, mutect2, varscan2
- CLIP4 | c.1271C>A p.S424Y | Missense Mutation (SNP) | VAF 149/547 reads (27%) | SIFT tolerated (0.3); PolyPhen benign (0.003); catalogued as COSV60750063; called by muse, mutect2, varscan2
- CLSTN2 | c.1029G>A p.W343* | Nonsense Mutation (SNP) | VAF 115/520 reads (22%) | catalogued as COSV101515950; called by muse, mutect2, varscan2
- CLYBL | c.23G>T p.R8M | Missense Mutation (SNP) | VAF 77/251 reads (31%) | SIFT tolerated, low confidence (0.05); PolyPhen benign (0.188); catalogued as rs1566586110; called by muse, mutect2, varscan2
- COQ3 | c.283G>T p.G95C | Missense Mutation (SNP) | VAF 95/374 reads (25%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.648); catalogued as COSV99632526, COSV99632639; called by muse, mutect2, varscan2
- CPS1 | c.2153G>T p.R718I | Missense Mutation (SNP) | VAF 49/211 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as CM114344, COSV51825265; called by muse, mutect2, varscan2
- CROCC2 | c.1873G>A p.A625T | Missense Mutation (SNP) | VAF 16/58 reads (28%) | SIFT tolerated (0.26); PolyPhen benign (0.006); catalogued as rs1053476559, COSV101407878; called by muse, varscan2
- CSKMT | c.167G>A p.G56E | Missense Mutation (SNP) | VAF 123/555 reads (22%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.976); catalogued as rs763451990; called by muse, mutect2, varscan2
- DAAM1 | c.1774G>T p.A592S | Missense Mutation (SNP) | VAF 39/170 reads (23%) | SIFT tolerated (0.55); PolyPhen benign (0.015); catalogued as COSV62836533; called by muse, mutect2, varscan2
- DAAM2 | c.2265C>G p.Y755* | Nonsense Mutation (SNP) | VAF 51/138 reads (37%) | catalogued as COSV99226138; called by muse, mutect2, varscan2
- DEF8 | c.755G>T p.S252I | Missense Mutation (SNP) | VAF 33/221 reads (15%) | SIFT tolerated (0.28); PolyPhen possibly damaging (0.683); catalogued as COSV51918102; called by muse, mutect2, varscan2
- DIS3L | c.334C>T p.H112Y (on ENST00000319212 / NM_001143688.3; = p.H29Y on NM_133375.5 and 5 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 74/269 reads (28%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.806); catalogued as rs746448504; called by muse, mutect2, varscan2
- DNAH14 | c.2118G>T p.M706I (on ENST00000445597; = p.M735I on NM_001367479.1) | Missense Mutation (SNP) | VAF 16/79 reads (20%) | SIFT tolerated (0.16); PolyPhen benign (0.001); catalogued as COSV101464739; called by muse, mutect2, varscan2
- DNAH3 | c.3850C>A p.Q1284K | Missense Mutation (SNP) | VAF 85/368 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (0.993); catalogued as COSV99770543; called by muse, mutect2, varscan2
- DNAH7 | c.8301C>G p.I2767M | Missense Mutation (SNP) | VAF 44/175 reads (25%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.738); catalogued as COSV56751539; called by muse, mutect2, varscan2
- DNAH7 | c.747G>T p.M249I | Missense Mutation (SNP) | VAF 15/38 reads (39%) | SIFT tolerated (0.5); PolyPhen benign (0); catalogued as COSV56780432; called by muse, mutect2
- DRD2 | c.356C>T p.T119M | Missense Mutation (SNP) | VAF 183/672 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (0.986); catalogued as rs1274176960, COSV60757889; called by muse, mutect2, varscan2
- DSEL | c.1406G>T p.G469V | Missense Mutation (SNP) | VAF 42/127 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs1365586737; called by muse, mutect2, varscan2
- EPHA3 | c.821G>T p.R274L | Missense Mutation (SNP) | VAF 25/79 reads (32%) | SIFT tolerated (0.24); PolyPhen benign (0.165); catalogued as COSV60709306; called by mutect2, varscan2
- EPHB1 | c.193G>T p.E65* | Nonsense Mutation (SNP) | VAF 18/81 reads (22%) | catalogued as COSV67665061; called by muse, mutect2, varscan2
- EXD3 | c.701C>T p.P234L | Missense Mutation (SNP) | VAF 82/371 reads (22%) | SIFT tolerated (0.08); PolyPhen benign (0.17); catalogued as rs368890121; called by muse, mutect2, varscan2
- FAN1 | c.2878G>T p.D960Y | Missense Mutation (SNP) | VAF 80/280 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as CM126659; called by muse, varscan2
- FAT3 | c.10894G>A p.D3632N | Missense Mutation (SNP) | VAF 79/282 reads (28%) | SIFT tolerated (0.06); PolyPhen probably damaging (0.966); catalogued as COSV53071096; called by muse, mutect2, varscan2
- FRMPD4 | c.1755C>A p.S585R | Missense Mutation (SNP) | VAF 70/338 reads (21%) | SIFT tolerated (0.17); PolyPhen benign (0.003); catalogued as COSV66215339; called by muse, mutect2, varscan2
- FSD1L | c.797-2A>T p.X266_splice | Splice Site (SNP) | VAF 34/150 reads (23%) | catalogued as COSV65997575; called by muse, mutect2, varscan2
- GREB1 | c.5173G>C p.V1725L | Missense Mutation (SNP) | VAF 146/483 reads (30%) | SIFT tolerated (0.08); PolyPhen benign (0.02); catalogued as COSV52180558; called by muse, mutect2, varscan2
- GRXCR1 | c.413G>T p.R138L | Missense Mutation (SNP) | VAF 93/344 reads (27%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.993); catalogued as COSV67670498; called by muse, mutect2, varscan2
- GTF3C5 | c.1034A>G p.Y345C | Missense Mutation (SNP) | VAF 67/264 reads (25%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.962); catalogued as rs1462291721; called by muse, mutect2, varscan2
- GZMH | c.607G>A p.G203R | Missense Mutation (SNP) | VAF 56/164 reads (34%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.973); catalogued as rs764634951, COSV53537509, COSV99361803; called by muse, varscan2
- HAVCR2 | c.711A>C p.L237F | Missense Mutation (SNP) | VAF 47/135 reads (35%) | SIFT tolerated (0.08); PolyPhen benign (0.36); catalogued as rs1301477579; called by muse, mutect2, varscan2
- HCK | c.173C>T p.T58I | Missense Mutation (SNP) | VAF 59/199 reads (30%) | SIFT tolerated (0.14); PolyPhen benign (0); catalogued as rs767954647; called by muse, mutect2, varscan2
- HMX1 | c.806C>G p.A269G | Missense Mutation (SNP) | VAF 61/238 reads (26%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.896); catalogued as rs13303190; called by muse, mutect2, varscan2
- HS3ST4 | c.1233G>T p.K411N | Missense Mutation (SNP) | VAF 185/705 reads (26%) | SIFT deleterious (0.01); PolyPhen probably damaging (1); catalogued as COSV100503261, COSV58807832; called by muse, mutect2, varscan2
- IGHV3-23 | c.47G>A p.G16D | Missense Mutation (SNP) | VAF 58/234 reads (25%) | SIFT deleterious, low confidence (0.03); PolyPhen benign (0.316); catalogued as rs782449353; called by muse, mutect2, varscan2
- ISL1 | c.847G>T p.E283* | Nonsense Mutation (SNP) | VAF 95/472 reads (20%) | catalogued as COSV57933743; called by muse, varscan2
- ITGAM | c.1706G>C p.S569T (on ENST00000648685 / NM_001145808.2; = p.S568T on NM_000632.4) | Missense Mutation (SNP) | VAF 120/448 reads (27%) | SIFT tolerated (0.06); PolyPhen benign (0.31); catalogued as COSV54943097; called by muse, mutect2, varscan2
- KIRREL3 | c.26T>A p.L9H | Missense Mutation (SNP) | VAF 37/143 reads (26%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.984); catalogued as rs960778002; called by muse, mutect2, varscan2
- LAMA2 | c.7150G>C p.D2384H | Missense Mutation (SNP) | VAF 114/386 reads (30%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.997); catalogued as COSV101370211; called by muse, mutect2, varscan2
- LAMC2 | c.2033G>T p.G678V | Missense Mutation (SNP) | VAF 136/475 reads (29%) | SIFT tolerated (0.27); PolyPhen benign (0.01); catalogued as COSV99918033; called by muse, mutect2, varscan2
- LIG3 | c.2762G>T p.R921L | Missense Mutation (SNP) | VAF 41/107 reads (38%) | SIFT tolerated (0.14); PolyPhen benign (0.289); catalogued as rs149236110; called by muse, mutect2, varscan2
- LRP1B | c.7951C>A p.L2651M | Missense Mutation (SNP) | VAF 55/269 reads (20%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.999); catalogued as rs1332939835, COSV67212818; called by muse, mutect2, varscan2
- MAGEB17 | c.597C>A p.S199R | Missense Mutation (SNP) | VAF 40/131 reads (31%) | SIFT deleterious (0); PolyPhen benign (0.18); catalogued as COSV61557179; called by muse, mutect2, varscan2
- MAGEB6 | c.671G>C p.C224S | Missense Mutation (SNP) | VAF 24/124 reads (19%) | SIFT tolerated (0.39); PolyPhen benign (0); catalogued as COSV66872527; called by muse, mutect2, varscan2
- MEN1 | c.529G>A p.D177N | Missense Mutation (SNP) | VAF 152/988 reads (15%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.984); catalogued as CM981258; called by muse, mutect2, varscan2
- MFSD3 | c.1029G>A p.M343I | Missense Mutation (SNP) | VAF 79/360 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (0.992); catalogued as rs149048424; called by muse, mutect2, varscan2
- MLH3 | c.2116A>G p.T706A | Missense Mutation (SNP) | VAF 61/210 reads (29%) | SIFT tolerated (0.16); PolyPhen benign (0.039); catalogued as CD1511833; called by muse, mutect2, varscan2
- MRGPRE | c.914G>T p.R305L | Missense Mutation (SNP) | VAF 6/18 reads (33%) | SIFT tolerated (0.23); PolyPhen benign (0.203); catalogued as rs779850836; called by muse, varscan2
- MRPS9 | c.979G>T p.D327Y | Missense Mutation (SNP) | VAF 39/142 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV99305830; called by muse, mutect2, varscan2
- MS4A14 | c.1807G>T p.D603Y | Missense Mutation (SNP) | VAF 77/279 reads (28%) | SIFT tolerated (0.79); PolyPhen benign (0.005); catalogued as COSV55733705, COSV55734924; called by muse, mutect2, varscan2
- MS4A14 | c.2001G>T p.R667S | Missense Mutation (SNP) | VAF 46/119 reads (39%) | SIFT deleterious, low confidence (0.05); PolyPhen benign (0.005); catalogued as COSV55734288; called by muse, mutect2, varscan2
- NAV3 | c.4329G>C p.W1443C | Missense Mutation (SNP) | VAF 69/267 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs560071209; called by muse, mutect2, varscan2
- NBEA | c.2011del p.R671Gfs*10 | Frame Shift Del (DEL) | VAF 16/62 reads (26%) | catalogued as rs1428467615; called by mutect2, pindel, varscan2
- NDUFA10 | c.401G>T p.W134L | Missense Mutation (SNP) | VAF 135/482 reads (28%) | SIFT tolerated (0.11); PolyPhen probably damaging (0.934); catalogued as COSV99401653; called by muse, mutect2, varscan2
- NEB | c.15124C>A p.R5042S | Missense Mutation (SNP) | VAF 33/151 reads (22%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.995); catalogued as COSV50814710; called by muse, mutect2, varscan2
- NETO1 | c.826C>T p.R276* | Nonsense Mutation (SNP) | VAF 105/326 reads (32%) | catalogued as rs1051379392, COSV55013594; called by muse, mutect2, varscan2
- NFASC | c.310C>A p.R104S (on ENST00000339876 / NM_001378329.1; = p.R98S on NM_015090.4 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 95/370 reads (26%) | SIFT tolerated (0.24); PolyPhen benign (0.176); catalogued as COSV58386460; called by muse, mutect2, varscan2
- NLGN4X | c.2217C>A p.H739Q | Missense Mutation (SNP) | VAF 130/568 reads (23%) | SIFT tolerated, low confidence (0.24); PolyPhen possibly damaging (0.608); catalogued as COSV52012665; called by muse, mutect2, varscan2
- NLRP6 | c.328G>T p.G110W | Missense Mutation (SNP) | VAF 22/53 reads (42%) | SIFT deleterious (0.01); PolyPhen benign (0.255); catalogued as COSV56461334; called by muse, mutect2, varscan2
- NOX5 | c.935A>G p.Q312R | Missense Mutation (SNP) | VAF 84/327 reads (26%) | SIFT tolerated (0.47); PolyPhen benign (0.084); catalogued as COSV52998893; called by muse, mutect2, varscan2
- NR0B1 | c.499C>T p.P167S | Missense Mutation (SNP) | VAF 189/732 reads (26%) | SIFT tolerated, low confidence (0.16); PolyPhen benign (0.007); catalogued as rs1266636471; called by muse, mutect2, varscan2
- NTNG1 | c.499G>A p.D167N | Missense Mutation (SNP) | VAF 83/288 reads (29%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.999); catalogued as rs1173408635, COSV53974489; called by muse, mutect2, varscan2
- OLFML2B | c.802G>T p.A268S | Missense Mutation (SNP) | VAF 114/474 reads (24%) | SIFT tolerated (0.31); PolyPhen benign (0.003); catalogued as COSV99669044; called by muse, mutect2, varscan2
- OR10K2 | c.46G>T p.G16C | Missense Mutation (SNP) | VAF 50/179 reads (28%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.97); catalogued as rs779658726, COSV59221384, COSV59221911; called by muse, mutect2
- OR4N5 | c.467C>A p.S156Y | Missense Mutation (SNP) | VAF 115/373 reads (31%) | SIFT deleterious (0); PolyPhen benign (0.052); catalogued as COSV61321154, COSV61321211; called by muse, mutect2, varscan2
- OR4S2 | c.236T>A p.M79K | Missense Mutation (SNP) | VAF 65/269 reads (24%) | SIFT deleterious (0); PolyPhen benign (0.263); catalogued as rs757223228; called by muse, mutect2, varscan2
- OR51E1 | c.428G>T p.R143L | Missense Mutation (SNP) | VAF 15/54 reads (28%) | SIFT tolerated (0.32); PolyPhen probably damaging (0.922); catalogued as rs779396777, COSV67810886; called by muse, mutect2, varscan2
- OR51M1 | c.302C>A p.S101Y | Missense Mutation (SNP) | VAF 107/354 reads (30%) | SIFT tolerated (0.34); PolyPhen benign (0.012); catalogued as rs564083259, COSV60784269; called by muse, mutect2, varscan2
- OR8D1 | c.173C>T p.P58L | Missense Mutation (SNP) | VAF 59/263 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs779143162, COSV63442135; called by muse, mutect2, varscan2
- PAX6 | c.658G>T p.E220* | Nonsense Mutation (SNP) | VAF 126/475 reads (27%) | catalogued as CM983677; called by muse, mutect2, varscan2
- PCARE | c.1402C>A p.H468N | Missense Mutation (SNP) | VAF 109/423 reads (26%) | SIFT tolerated (0.36); PolyPhen benign (0.074); catalogued as COSV100527515; called by muse, mutect2, varscan2
- PDE11A | c.2627T>A p.I876N | Missense Mutation (SNP) | VAF 82/355 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (0.97); catalogued as rs1346951139; called by muse, mutect2, varscan2
- PDZRN4 | c.2812G>C p.G938R (on ENST00000402685 / NM_001164595.2; = p.G680R on NM_013377.4) | Missense Mutation (SNP) | VAF 94/442 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV54213961; called by muse, mutect2, varscan2
- PHF21B | c.1200C>T p.A400= | Splice Region (SNP) | VAF 37/191 reads (19%) | catalogued as rs771252146; called by muse, mutect2, varscan2
- PHKA2 | c.1541G>T p.R514M | Missense Mutation (SNP) | VAF 77/338 reads (23%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.677); catalogued as COSV66052817; called by muse, mutect2, varscan2
- PITPNM3 | c.875G>A p.R292Q | Missense Mutation (SNP) | VAF 16/268 reads (6%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.47); catalogued as rs769346914; called by muse, mutect2
- PKHD1L1 | c.6093A>G p.I2031M | Missense Mutation (SNP) | VAF 58/224 reads (26%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.78); catalogued as rs1179677750; called by muse, mutect2, varscan2
- PLSCR1 | c.166C>G p.P56A | Missense Mutation (SNP) | VAF 87/420 reads (21%) | SIFT tolerated (0.27); PolyPhen benign (0); catalogued as rs1283648213; called by muse, mutect2, varscan2
- POU6F2 | c.283-1G>A p.X95_splice | Splice Site (SNP) | VAF 43/141 reads (30%) | catalogued as rs897241407; called by muse, mutect2, varscan2
- PSCA | c.227C>T p.T76M | Missense Mutation (SNP) | VAF 52/184 reads (28%) | SIFT deleterious (0); PolyPhen probably damaging (0.985); catalogued as rs372257395; called by muse, mutect2, varscan2
- PTTG2 | c.28G>C p.E10Q | Missense Mutation (SNP) | VAF 42/137 reads (31%) | SIFT deleterious (0); PolyPhen probably damaging (0.969); catalogued as COSV54714357; called by muse, mutect2, varscan2
- RAPGEF4 | c.2354G>T p.W785L | Missense Mutation (SNP) | VAF 60/200 reads (30%) | SIFT deleterious (0); PolyPhen probably damaging (0.945); catalogued as COSV51381742; called by muse, mutect2, varscan2
- RAVER1 | c.524A>T p.Y175F | Missense Mutation (SNP) | VAF 125/513 reads (24%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.705); catalogued as rs1186728432; called by muse, mutect2, varscan2
- RELN | c.5218A>T p.R1740W | Missense Mutation (SNP) | VAF 135/370 reads (36%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.991); catalogued as COSV59023716; called by mutect2, varscan2
- RET | c.1649-1G>T p.X550_splice | Splice Site (SNP) | VAF 184/755 reads (24%) | catalogued as CS050822, COSV60690041; called by muse, mutect2, varscan2
- RGSL1 | c.1303C>A p.L435I | Missense Mutation (SNP) | VAF 57/301 reads (19%) | SIFT tolerated (0.23); PolyPhen benign (0.241); catalogued as COSV54258224; called by muse, mutect2, varscan2
- ROCK1 | c.2926G>T p.E976* | Nonsense Mutation (SNP) | VAF 17/100 reads (17%) | catalogued as COSV67695209; called by muse, mutect2, varscan2
- RPH3A | c.1124C>T p.P375L (on ENST00000389385 / NM_001143854.2; = p.P371L on NM_014954.4 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 35/105 reads (33%) | SIFT deleterious (0.02); PolyPhen benign (0.036); catalogued as rs762909268; called by muse, mutect2, varscan2
- SALL1 | c.2491G>T p.D831Y | Missense Mutation (SNP) | VAF 99/414 reads (24%) | SIFT deleterious (0); PolyPhen possibly damaging (0.798); catalogued as COSV51756863; called by muse, mutect2, varscan2
- SEC23B | c.1225G>T p.D409Y | Missense Mutation (SNP) | VAF 44/293 reads (15%) | SIFT deleterious (0); PolyPhen possibly damaging (0.608); catalogued as COSV52722040; called by muse, mutect2, varscan2
- SEMA3D | c.194C>A p.S65* | Nonsense Mutation (SNP) | VAF 63/159 reads (40%) | catalogued as COSV52408307; called by muse, mutect2, varscan2
- SEMA5B | c.2931C>A p.C977* | Nonsense Mutation (SNP) | VAF 52/278 reads (19%) | catalogued as COSV52102531; called by muse, mutect2, varscan2
- SF3B1 | c.911C>A p.P304H | Missense Mutation (SNP) | VAF 82/269 reads (30%) | SIFT deleterious (0); PolyPhen probably damaging (0.968); catalogued as COSV59209054; called by muse, mutect2, varscan2
- SLC26A6 | c.998del p.P333Qfs*36 | Frame Shift Del (DEL) | VAF 106/235 reads (45%) | catalogued as rs1353702420; called by mutect2, pindel, varscan2
- SLCO1B3-SLCO1B7 | c.2047G>T p.G683* (on ENST00000540229 / NM_001371097.1; = p.G622* on NM_001009562.4) | Nonsense Mutation (SNP) | VAF 12/68 reads (18%) | catalogued as COSV67442634; called by muse, mutect2, varscan2
- SORCS3 | c.2977G>T p.E993* | Nonsense Mutation (SNP) | VAF 46/182 reads (25%) | catalogued as COSV63793149, COSV63796811; called by muse, mutect2, varscan2
- SPANXN2 | c.502G>A p.D168N | Missense Mutation (SNP) | VAF 114/339 reads (34%) | SIFT tolerated, low confidence (0.68); PolyPhen benign (0.419); catalogued as COSV65128364; called by muse, varscan2
- SPHKAP | c.581C>A p.T194K | Missense Mutation (SNP) | VAF 72/295 reads (24%) | SIFT deleterious (0.03); PolyPhen benign (0.013); catalogued as COSV100764486; called by muse, mutect2, varscan2
- SRSF3 | c.287G>T p.W96L | Missense Mutation (SNP) | VAF 104/293 reads (35%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.901); catalogued as rs1281096576; called by muse, mutect2, varscan2
- SULT1C2 | c.876C>G p.F292L | Missense Mutation (SNP) | VAF 35/110 reads (32%) | SIFT deleterious (0.03); PolyPhen benign (0.445); catalogued as COSV52267226; called by muse, mutect2, varscan2
- SUSD2 | c.783G>A p.K261= | Splice Region (SNP) | VAF 123/445 reads (28%) | catalogued as rs763071579; called by muse, mutect2, varscan2
- SV2B | c.732G>T p.M244I | Missense Mutation (SNP) | VAF 18/98 reads (18%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.876); catalogued as rs772607628; called by muse, mutect2, varscan2
- TDRD5 | c.544G>C p.A182P | Missense Mutation (SNP) | VAF 43/229 reads (19%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.995); catalogued as COSV54238253; called by muse, mutect2, varscan2
- TENM3 | c.1646G>T p.C549F | Missense Mutation (SNP) | VAF 74/202 reads (37%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV69309437; called by muse, mutect2, varscan2
- TET2 | c.3782G>T p.R1261L | Missense Mutation (SNP) | VAF 79/204 reads (39%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV54395386, COSV54396706, COSV99485827; called by muse, mutect2, varscan2
- TMEM132E | c.142C>A p.R48S | Missense Mutation (SNP) | VAF 128/288 reads (44%) | SIFT tolerated (0.07); PolyPhen possibly damaging (0.472); catalogued as rs553628300, COSV100396269; called by muse, mutect2, varscan2
- TNC | c.5018G>T p.R1673L | Missense Mutation (SNP) | VAF 138/513 reads (27%) | SIFT tolerated (0.07); PolyPhen probably damaging (1); catalogued as COSV60788565; called by muse, mutect2, varscan2
- TNN | c.592G>T p.G198C | Missense Mutation (SNP) | VAF 142/496 reads (29%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.862); catalogued as rs770960847; called by muse, mutect2, varscan2
- TNN | c.1426C>A p.R476S | Missense Mutation (SNP) | VAF 67/272 reads (25%) | SIFT tolerated (0.39); PolyPhen possibly damaging (0.555); catalogued as COSV53426279; called by muse, mutect2, varscan2
- TRO | c.1070C>A p.T357N | Missense Mutation (SNP) | VAF 93/415 reads (22%) | SIFT tolerated (0.07); PolyPhen benign (0.054); catalogued as COSV51505137; called by muse, mutect2, varscan2
- TTLL9 | c.290G>T p.R97L | Missense Mutation (SNP) | VAF 59/263 reads (22%) | SIFT deleterious (0); PolyPhen possibly damaging (0.678); catalogued as COSV100207032; called by muse, mutect2, varscan2
- TUBB8B | c.485G>A p.R162K | Missense Mutation (SNP) | VAF 146/882 reads (17%) | SIFT deleterious, low confidence (0.01); PolyPhen probably damaging (0.941); catalogued as rs1299711770; called by muse, varscan2
- UGT1A5 | c.123G>T p.W41C | Missense Mutation (SNP) | VAF 116/441 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV59388214; called by muse, mutect2
- USH2A | c.4092C>G p.F1364L | Missense Mutation (SNP) | VAF 72/309 reads (23%) | SIFT tolerated (0.18); PolyPhen benign (0.003); catalogued as COSV56348219; called by muse, mutect2, varscan2
- VCAM1 | c.1334C>A p.T445N | Missense Mutation (SNP) | VAF 51/240 reads (21%) | SIFT tolerated (0.44); PolyPhen possibly damaging (0.446); catalogued as COSV54121003; called by muse, mutect2, varscan2
- VPS13D | c.3109G>T p.D1037Y | Missense Mutation (SNP) | VAF 95/326 reads (29%) | SIFT deleterious (0); PolyPhen possibly damaging (0.878); catalogued as COSV50663900; called by muse, mutect2, varscan2
- YY1AP1 | c.1744G>A p.A582T (on ENST00000295566 / NM_139118.2; = p.A525T on NM_018253.3 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 65/283 reads (23%) | SIFT tolerated, low confidence (0.57); PolyPhen benign (0.04); catalogued as rs766914733; called by muse, mutect2, varscan2
- ZIC1 | c.944G>C p.R315P | Missense Mutation (SNP) | VAF 76/496 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (0.981); catalogued as COSV51551053; called by muse, mutect2, varscan2
- ZNF202 | c.1712G>T p.G571V | Missense Mutation (SNP) | VAF 63/226 reads (28%) | SIFT deleterious (0); PolyPhen probably damaging (0.936); catalogued as COSV60249047; called by muse, mutect2, varscan2
- ZNF740 | c.122G>T p.R41L | Missense Mutation (SNP) | VAF 104/373 reads (28%) | SIFT deleterious (0.03); PolyPhen benign (0.006); catalogued as rs1342199742; called by muse, mutect2, varscan2
- A1CF | c.653C>A p.P218Q | Missense Mutation (SNP) | VAF 7/20 reads (35%) | SIFT deleterious (0); PolyPhen probably damaging (0.958); called by muse, mutect2
- ABCA2 | c.796G>T p.E266* (on ENST00000614293; = p.E236* on NM_001606.5 and 1 other RefSeq transcript) | Nonsense Mutation (SNP) | VAF 78/330 reads (24%) | called by muse, mutect2, varscan2
- ABLIM3 | c.1791A>T p.T597= | Splice Region (SNP) | VAF 76/245 reads (31%) | called by muse, mutect2, varscan2
- ADGRF4 | c.1757G>T p.R586M | Missense Mutation (SNP) | VAF 30/102 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- ADGRL3 | c.1499C>T p.P500L (on ENST00000506720 / NM_001322402.2; = p.P432L on NM_015236.6) | Missense Mutation (SNP) | VAF 79/238 reads (33%) | SIFT deleterious (0.04); PolyPhen benign (0.001); called by muse, mutect2, varscan2
- ADGRV1 | c.12376G>T p.D4126Y | Missense Mutation (SNP) | VAF 60/146 reads (41%) | SIFT deleterious (0); PolyPhen possibly damaging (0.556); called by muse, mutect2, varscan2
- AGBL4 | c.631C>A p.P211T | Missense Mutation (SNP) | VAF 87/400 reads (22%) | SIFT tolerated (0.11); PolyPhen benign (0.065); called by muse, mutect2, varscan2
- AHNAK2 | c.11470G>T p.A3824S | Missense Mutation (SNP) | VAF 211/875 reads (24%) | SIFT tolerated (0.08); PolyPhen possibly damaging (0.795); called by muse, mutect2, varscan2
- ALAS2 | c.1451C>G p.A484G | Missense Mutation (SNP) | VAF 106/392 reads (27%) | SIFT tolerated (0.24); PolyPhen benign (0.012); called by muse, mutect2, varscan2
- ALAS2 | c.955C>A p.P319T | Missense Mutation (SNP) | VAF 65/293 reads (22%) | SIFT deleterious (0.03); PolyPhen benign (0.047); called by muse, varscan2
- ALPK2 | c.679C>T p.Q227* | Nonsense Mutation (SNP) | VAF 87/245 reads (36%) | called by muse, mutect2, varscan2
- AMY2B | c.968G>T p.G323V | Missense Mutation (SNP) | VAF 119/460 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- ANKK1 | c.1496A>T p.H499L | Missense Mutation (SNP) | VAF 88/312 reads (28%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- ANTXRL | c.964G>T p.E322* | Nonsense Mutation (SNP) | VAF 11/40 reads (28%) | called by muse, mutect2, varscan2
- APBA1 | c.1788T>C p.D596= | Splice Region (SNP) | VAF 93/377 reads (25%) | called by muse, mutect2, varscan2
- ARHGAP42 | c.2279T>C p.V760A | Missense Mutation (SNP) | VAF 77/256 reads (30%) | SIFT tolerated (0.87); PolyPhen benign (0); called by muse, mutect2, varscan2
- ASXL3 | c.761C>G p.P254R | Missense Mutation (SNP) | VAF 25/166 reads (15%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- ATF7IP | c.844G>A p.E282K | Missense Mutation (SNP) | VAF 40/122 reads (33%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.786); called by muse, mutect2, varscan2
- ATIC | c.493G>T p.D165Y | Missense Mutation (SNP) | VAF 73/264 reads (28%) | SIFT deleterious (0); PolyPhen probably damaging (0.989); called by muse, mutect2, varscan2
- ATP10A | c.1912G>T p.G638C | Missense Mutation (SNP) | VAF 102/494 reads (21%) | SIFT tolerated (0.08); PolyPhen benign (0.021); called by muse, varscan2
- ATP10A | c.1911G>T p.L637F | Missense Mutation (SNP) | VAF 102/502 reads (20%) | SIFT tolerated (0.22); PolyPhen benign (0.001); called by muse, mutect2, varscan2
- BAAT | c.914G>T p.G305V | Missense Mutation (SNP) | VAF 133/738 reads (18%) | SIFT tolerated (0.22); PolyPhen benign (0.124); called by muse, mutect2, varscan2
- BRINP3 | c.2121A>T p.R707S | Missense Mutation (SNP) | VAF 40/132 reads (30%) | SIFT deleterious (0); PolyPhen probably damaging (0.95); called by muse, mutect2, varscan2
- C11orf96 | c.722C>A p.A241D | Missense Mutation (SNP) | VAF 20/88 reads (23%) | SIFT tolerated, low confidence (0.15); called by muse, mutect2, varscan2
- C20orf96 | c.849G>T p.E283D (on ENST00000360321 / NM_153269.3; = p.E282D on NM_080571.1) | Missense Mutation (SNP) | VAF 24/174 reads (14%) | SIFT tolerated (0.08); PolyPhen benign (0.053); called by muse, mutect2, varscan2
- C5orf22 | c.807G>T p.Q269H | Missense Mutation (SNP) | VAF 10/85 reads (12%) | SIFT deleterious (0); PolyPhen possibly damaging (0.903); called by muse, mutect2, varscan2
- CADPS | c.1203+1G>C p.X401_splice | Splice Site (SNP) | VAF 35/120 reads (29%) | called by muse, mutect2, varscan2
- CAMTA1 | c.2716T>C p.F906L | Missense Mutation (SNP) | VAF 67/267 reads (25%) | SIFT deleterious (0); PolyPhen benign (0.253); called by muse, mutect2, varscan2
- CASZ1 | c.3973A>T p.M1325L | Missense Mutation (SNP) | VAF 95/239 reads (40%) | SIFT tolerated (0.16); PolyPhen possibly damaging (0.527); called by muse, mutect2, varscan2
- CBX6 | c.1210G>T p.G404C | Missense Mutation (SNP) | VAF 41/128 reads (32%) | SIFT deleterious, low confidence (0.01); PolyPhen possibly damaging (0.478); called by muse, mutect2, varscan2
- CCDC58 | c.254T>A p.L85H | Missense Mutation (SNP) | VAF 85/438 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- CCDC59 | c.17G>C p.R6P | Missense Mutation (SNP) | VAF 77/346 reads (22%) | SIFT tolerated (0.63); PolyPhen benign (0); called by muse, mutect2, varscan2
- CCDC82 | c.1186A>G p.S396G | Missense Mutation (SNP) | VAF 22/96 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (0.987); called by muse, mutect2, varscan2
- CD33 | c.869C>A p.A290D | Missense Mutation (SNP) | VAF 106/194 reads (55%) | SIFT deleterious (0.02); PolyPhen benign (0.17); called by muse, mutect2, varscan2
- CDH10 | c.913G>T p.E305* | Nonsense Mutation (SNP) | VAF 36/311 reads (12%) | called by muse, mutect2, varscan2
- CDKL5 | c.749C>A p.P250Q | Missense Mutation (SNP) | VAF 72/341 reads (21%) | SIFT deleterious, low confidence (0.01); PolyPhen probably damaging (0.99); called by muse, mutect2, varscan2
- CDO1 | c.295C>G p.Q99E | Missense Mutation (SNP) | VAF 28/114 reads (25%) | SIFT tolerated (0.44); PolyPhen benign (0.323); called by muse, mutect2, varscan2
- CDON | c.962A>T p.Q321L | Missense Mutation (SNP) | VAF 56/234 reads (24%) | SIFT tolerated (0.21); PolyPhen benign (0.031); called by muse, mutect2, varscan2
- CELF6 | c.691G>T p.G231C | Missense Mutation (SNP) | VAF 76/236 reads (32%) | SIFT deleterious (0); PolyPhen probably damaging (0.989); called by muse, mutect2, varscan2
- CFAP44 | c.2620_2626dup p.A876Gfs*17 | Frame Shift Ins (INS) | VAF 84/258 reads (33%) | called by mutect2, varscan2
- CFAP47 | c.2177C>G p.S726* | Nonsense Mutation (SNP) | VAF 32/154 reads (21%) | called by muse, mutect2, varscan2
- CFAP61 | c.3037C>A p.L1013I | Missense Mutation (SNP) | VAF 57/217 reads (26%) | SIFT tolerated (0.06); PolyPhen benign (0.158); called by muse, mutect2, varscan2
- CFP | c.29G>C p.R10P | Missense Mutation (SNP) | VAF 171/706 reads (24%) | SIFT tolerated, low confidence (0.23); PolyPhen benign (0); called by muse, mutect2, varscan2
- CHD9 | c.6345C>G p.N2115K | Missense Mutation (SNP) | VAF 39/139 reads (28%) | SIFT tolerated, low confidence (0.06); PolyPhen probably damaging (0.986); called by muse, mutect2, varscan2
- CHRM3 | c.1308C>A p.D436E | Missense Mutation (SNP) | VAF 93/413 reads (23%) | SIFT tolerated (0.84); PolyPhen benign (0.003); called by muse, mutect2, varscan2
- CLCA1 | c.701A>C p.K234T | Missense Mutation (SNP) | VAF 49/145 reads (34%) | SIFT tolerated (0.41); PolyPhen benign (0.414); called by muse, mutect2, varscan2
- CLPB | c.1761G>T p.W587C | Missense Mutation (SNP) | VAF 72/245 reads (29%) | SIFT deleterious (0.02); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- CLUAP1 | c.1037G>T p.G346V | Missense Mutation (SNP) | VAF 42/200 reads (21%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.84); called by muse, varscan2
- CNTN3 | c.3011C>G p.S1004* | Nonsense Mutation (SNP) | VAF 15/54 reads (28%) | called by muse, mutect2, varscan2
- COL20A1 | c.1697C>A p.S566* | Nonsense Mutation (SNP) | VAF 38/140 reads (27%) | called by muse, mutect2, varscan2
- COL22A1 | c.1531G>C p.G511R | Missense Mutation (SNP) | VAF 94/424 reads (22%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- COL6A6 | c.1213A>T p.K405* | Nonsense Mutation (SNP) | VAF 126/309 reads (41%) | called by muse, mutect2, varscan2
- CRMP1 | c.241C>G p.Q81E | Missense Mutation (SNP) | VAF 75/324 reads (23%) | SIFT tolerated (0.07); PolyPhen benign (0.003); called by muse, mutect2, varscan2
- CROCC2 | c.1792-1G>T p.X598_splice | Splice Site (SNP) | VAF 26/93 reads (28%) | called by muse, varscan2
- CSMD2 | c.7066C>G p.P2356A | Missense Mutation (SNP) | VAF 62/200 reads (31%) | SIFT tolerated (0.06); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- CSMD3 | c.1342+2T>A p.X448_splice | Splice Site (SNP) | VAF 27/105 reads (26%) | called by muse, mutect2, varscan2
- CSTF2T | c.650C>G p.P217R | Missense Mutation (SNP) | VAF 142/510 reads (28%) | SIFT deleterious (0.02); PolyPhen benign (0.326); called by muse, mutect2, varscan2
- CTNND2 | c.3155C>A p.S1052Y | Missense Mutation (SNP) | VAF 124/692 reads (18%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.974); called by muse, varscan2
- CTSF | c.532-5T>C | Splice Region (SNP) | VAF 30/214 reads (14%) | called by muse, mutect2, varscan2
- CYP11B1 | c.164T>A p.I55N | Missense Mutation (SNP) | VAF 255/1091 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (0.983); called by muse, mutect2, varscan2
- CYP19A1 | c.635C>A p.A212D | Missense Mutation (SNP) | VAF 55/255 reads (22%) | SIFT tolerated (0.63); PolyPhen benign (0.003); called by muse, mutect2, varscan2
- DDHD1 | c.586G>T p.V196L (on ENST00000323669; = p.V393L on NM_030637.3) | Missense Mutation (SNP) | VAF 37/141 reads (26%) | SIFT tolerated (0.24); PolyPhen benign (0.01); called by muse, mutect2, varscan2
- DEFB115 | c.237C>A p.D79E | Missense Mutation (SNP) | VAF 17/53 reads (32%) | SIFT tolerated (1); PolyPhen benign (0.001); called by muse, mutect2, varscan2
- DENND4A | c.2401C>A p.Q801K | Missense Mutation (SNP) | VAF 104/358 reads (29%) | SIFT tolerated (0.25); PolyPhen benign (0.099); called by muse, mutect2, varscan2
- DGKI | c.1466T>C p.V489A | Missense Mutation (SNP) | VAF 133/276 reads (48%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.994); called by muse, mutect2, varscan2
- DISP3 | c.2764T>A p.F922I | Missense Mutation (SNP) | VAF 76/329 reads (23%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.991); called by muse, mutect2, varscan2
- DNAH12 | c.4666G>C p.E1556Q (on ENST00000351747; = p.E1579Q on NM_001366028.2) | Missense Mutation (SNP) | VAF 39/141 reads (28%) | SIFT tolerated (0.07); PolyPhen benign (0.054); called by muse, mutect2, varscan2
- DNAH14 | c.877A>T p.K293* (on ENST00000445597; = p.K166* on NM_144989.3 and 2 other RefSeq transcripts) | Nonsense Mutation (SNP) | VAF 50/145 reads (34%) | called by muse, mutect2, varscan2
- DNAH5 | c.3130G>T p.V1044F | Missense Mutation (SNP) | VAF 153/785 reads (19%) | SIFT deleterious (0); PolyPhen possibly damaging (0.753); called by muse, mutect2, varscan2
- DNAH9 | c.11569A>G p.M3857V | Missense Mutation (SNP) | VAF 43/124 reads (35%) | SIFT tolerated (0.11); PolyPhen benign (0.003); called by muse, mutect2, varscan2
- DNAJC25 | c.820G>T p.G274C | Missense Mutation (SNP) | VAF 17/99 reads (17%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.963); called by muse, mutect2, varscan2
- DNAJC25 | c.821G>T p.G274V | Missense Mutation (SNP) | VAF 17/100 reads (17%) | SIFT deleterious (0.05); PolyPhen probably damaging (0.928); called by muse, mutect2, varscan2
- DPF3 | c.100G>T p.E34* | Nonsense Mutation (SNP) | VAF 47/208 reads (23%) | called by muse, mutect2, varscan2
- DPP10 | c.442-2A>T p.X148_splice | Splice Site (SNP) | VAF 8/34 reads (24%) | called by muse, mutect2
- DSCAML1 | c.1090G>A p.E364K (on ENST00000321322; = p.E304K on NM_020693.4) | Missense Mutation (SNP) | VAF 119/460 reads (26%) | SIFT tolerated (0.52); PolyPhen possibly damaging (0.81); called by muse, mutect2, varscan2
- DSEL | c.1405G>T p.G469W | Missense Mutation (SNP) | VAF 42/127 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- DST | c.2095_2110del p.D699Lfs*2 (on ENST00000361203 / NM_001374722.1; = p.D373Lfs*2 on NM_001723.6) | Frame Shift Del (DEL) | VAF 80/334 reads (24%) | called by mutect2, pindel, varscan2
- DSTYK | c.342A>G p.I114M | Missense Mutation (SNP) | VAF 83/302 reads (27%) | SIFT deleterious (0); PolyPhen possibly damaging (0.854); called by muse, mutect2, varscan2
- DYNC1I1 | c.1842_1851del p.N615Gfs*169 | Frame Shift Del (DEL) | VAF 63/183 reads (34%) | called by mutect2, pindel, varscan2
- EFHB | c.364del p.H122Mfs*4 | Frame Shift Del (DEL) | VAF 106/372 reads (28%) | called by mutect2, pindel, varscan2
- ELAVL4 | c.586C>A p.Q196K | Missense Mutation (SNP) | VAF 97/568 reads (17%) | SIFT tolerated (0.48); PolyPhen benign (0.007); called by muse, mutect2, varscan2
- EMB | c.707G>T p.W236L | Missense Mutation (SNP) | VAF 87/407 reads (21%) | SIFT deleterious (0.05); PolyPhen benign (0.062); called by muse, mutect2, varscan2
- EPHB1 | c.1445C>G p.S482C | Missense Mutation (SNP) | VAF 32/130 reads (25%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.823); called by muse, mutect2, varscan2
- ERICH4 | c.377T>A p.F126Y | Missense Mutation (SNP) | VAF 323/642 reads (50%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); called by muse, mutect2, varscan2
- ERMARD | c.580G>C p.A194P | Missense Mutation (SNP) | VAF 48/230 reads (21%) | SIFT tolerated (0.07); PolyPhen probably damaging (0.977); called by muse, mutect2, varscan2
- ETV3L | c.550C>T p.P184S | Missense Mutation (SNP) | VAF 65/231 reads (28%) | SIFT tolerated (0.18); PolyPhen benign (0); called by muse, mutect2, varscan2
- EVX2 | c.1070C>A p.A357D | Missense Mutation (SNP) | VAF 8/58 reads (14%) | SIFT deleterious, low confidence (0.01); PolyPhen possibly damaging (0.72); called by muse, mutect2
- FAM120C | c.1693G>A p.V565I | Missense Mutation (SNP) | VAF 81/406 reads (20%) | SIFT tolerated (0.37); PolyPhen benign (0.006); called by muse, mutect2, varscan2
- FAM13C | c.562A>T p.S188C | Missense Mutation (SNP) | VAF 91/336 reads (27%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.897); called by muse, mutect2, varscan2
- FAM47A | c.380C>A p.A127D | Missense Mutation (SNP) | VAF 33/131 reads (25%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.891); called by muse, mutect2, varscan2
- FBL | c.265G>A p.E89K | Missense Mutation (SNP) | VAF 27/238 reads (11%) | SIFT tolerated (0.09); PolyPhen benign (0.076); called by muse, mutect2, varscan2
- FBXW9 | c.953C>T p.A318V (on ENST00000587955; = p.A298V on NM_032301.3) | Missense Mutation (SNP) | VAF 220/1198 reads (18%) | SIFT tolerated (0.1); PolyPhen benign (0.242); called by muse, mutect2, varscan2
- FCRL1 | c.1031G>T p.R344M | Missense Mutation (SNP) | VAF 29/143 reads (20%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.946); called by muse, mutect2, varscan2
- FGF12 | c.613+1G>T p.X205_splice (on ENST00000454309 / NM_021032.5; = p.X143_splice on NM_004113.6) | Splice Site (SNP) | VAF 16/114 reads (14%) | called by muse, mutect2
- FGL2 | c.211C>T p.Q71* | Nonsense Mutation (SNP) | VAF 122/276 reads (44%) | called by muse, mutect2, varscan2
- FKBP9 | c.292C>A p.L98I | Missense Mutation (SNP) | VAF 22/428 reads (5%) | SIFT tolerated (0.09); PolyPhen possibly damaging (0.597); called by muse, mutect2
- FLNC | c.4301G>C p.R1434P | Missense Mutation (SNP) | VAF 197/339 reads (58%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.762); called by muse, mutect2, varscan2
- FMN2 | c.5105C>A p.S1702* | Nonsense Mutation (SNP) | VAF 22/116 reads (19%) | called by muse, varscan2
- FMR1NB | c.535G>C p.D179H | Missense Mutation (SNP) | VAF 63/204 reads (31%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- FNBP1L | c.455A>G p.Q152R | Missense Mutation (SNP) | VAF 23/94 reads (24%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.969); called by muse, mutect2, varscan2
- FOLH1B | n.1413dup | Splice Region (INS) | VAF 18/100 reads (18%) | called by mutect2, pindel
- FOXN3 | c.157C>A p.R53S | Missense Mutation (SNP) | VAF 64/206 reads (31%) | called by muse, mutect2, varscan2
- FOXP3 | c.651C>A p.H217Q | Missense Mutation (SNP) | VAF 131/616 reads (21%) | SIFT deleterious (0); PolyPhen benign (0.38); called by muse, mutect2, varscan2
- FPGS | c.1300G>T p.D434Y | Missense Mutation (SNP) | VAF 24/124 reads (19%) | SIFT deleterious (0); PolyPhen possibly damaging (0.819); called by muse, mutect2, varscan2
- FREM2 | c.6826G>T p.V2276L | Missense Mutation (SNP) | VAF 74/185 reads (40%) | SIFT deleterious (0); PolyPhen probably damaging (0.967); called by muse, mutect2, varscan2
- FSTL5 | c.892A>T p.N298Y | Missense Mutation (SNP) | VAF 12/26 reads (46%) | SIFT deleterious (0); PolyPhen possibly damaging (0.824); called by muse, varscan2
- FYB1 | c.1760C>A p.P587H | Missense Mutation (SNP) | VAF 52/126 reads (41%) | SIFT tolerated (0.62); PolyPhen benign (0.003); called by muse, mutect2, varscan2
- GALK1 | c.944+7C>A | Splice Region (SNP) | VAF 215/1147 reads (19%) | called by muse, mutect2, varscan2
- GALR3 | c.64G>A p.V22M | Missense Mutation (SNP) | VAF 58/184 reads (32%) | SIFT tolerated (0.21); PolyPhen probably damaging (0.936); called by muse, mutect2, varscan2
- GC | c.711A>G p.I237M | Missense Mutation (SNP) | VAF 46/106 reads (43%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.975); called by muse, mutect2, varscan2
- GLB1L3 | c.1621G>T p.G541C | Missense Mutation (SNP) | VAF 58/286 reads (20%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.76); called by muse, mutect2, varscan2
- GLIPR1 | c.344C>G p.T115R | Missense Mutation (SNP) | VAF 88/355 reads (25%) | SIFT tolerated (0.14); PolyPhen benign (0.021); called by muse, mutect2, varscan2
- GOLGA6L22 | c.2063T>A p.I688K | Missense Mutation (SNP) | VAF 222/1177 reads (19%) | SIFT deleterious (0.01); called by muse, varscan2
- GOLGA8T | c.1270G>T p.G424W | Missense Mutation (SNP) | VAF 110/730 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); called by muse, mutect2, varscan2
- GPR149 | c.1900G>A p.V634M | Missense Mutation (SNP) | VAF 37/176 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); called by muse, mutect2, varscan2
- GPR32 | c.315G>T p.R105S | Missense Mutation (SNP) | VAF 310/596 reads (52%) | SIFT tolerated (0.2); PolyPhen benign (0.103); called by muse, mutect2, varscan2
- GRIN2A | c.1081C>A p.L361M | Missense Mutation (SNP) | VAF 156/568 reads (27%) | SIFT tolerated (0.32); PolyPhen probably damaging (0.994); called by muse, varscan2
- GRXCR1 | c.94G>T p.V32L | Missense Mutation (SNP) | VAF 35/134 reads (26%) | SIFT deleterious (0.04); PolyPhen benign (0.092); called by muse, mutect2, varscan2
- HEATR4 | c.1003G>T p.V335L | Missense Mutation (SNP) | VAF 82/237 reads (35%) | SIFT tolerated (0.32); PolyPhen benign (0.236); called by muse, mutect2, varscan2
- HECW2 | c.1739C>G p.A580G | Missense Mutation (SNP) | VAF 5/25 reads (20%) | SIFT tolerated, low confidence (0.17); PolyPhen benign (0); called by muse, mutect2
- HERC2 | c.11291G>C p.S3764T | Missense Mutation (SNP) | VAF 58/231 reads (25%) | SIFT tolerated (0.08); PolyPhen benign (0.224); called by muse, mutect2, varscan2
- HERC2 | c.1870+1G>T p.X624_splice | Splice Site (SNP) | VAF 60/199 reads (30%) | called by muse, mutect2, varscan2
- HIVEP1 | c.6256G>A p.G2086R | Missense Mutation (SNP) | VAF 4/58 reads (7%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2
- HK1 | c.556G>A p.V186I | Missense Mutation (SNP) | VAF 191/703 reads (27%) | SIFT deleterious (0); PolyPhen possibly damaging (0.769); called by muse, mutect2, varscan2
- HNRNPA0 | c.50A>T p.Q17L | Missense Mutation (SNP) | VAF 72/164 reads (44%) | SIFT deleterious (0); PolyPhen benign (0.348); called by muse, mutect2, varscan2
- HOOK2 | c.1497G>T p.L499F | Missense Mutation (SNP) | VAF 99/367 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (0.981); called by muse, mutect2, varscan2
- HOXC8 | c.490C>A p.L164I | Missense Mutation (SNP) | VAF 100/438 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); called by muse, mutect2, varscan2
- HOXD12 | c.152G>T p.W51L | Missense Mutation (SNP) | VAF 36/177 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); called by muse, mutect2, varscan2
- HS3ST4 | c.348G>T p.E116D | Missense Mutation (SNP) | VAF 32/92 reads (35%) | SIFT tolerated, low confidence (0.08); PolyPhen benign (0); called by muse, mutect2, varscan2
- HS6ST1 | c.1030G>A p.D344N | Missense Mutation (SNP) | VAF 147/647 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); called by muse, mutect2, varscan2
- HUWE1 | c.5638C>A p.R1880S | Missense Mutation (SNP) | VAF 54/218 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); called by muse, mutect2, varscan2
- IFNA21 | c.397C>A p.P133T | Missense Mutation (SNP) | VAF 153/451 reads (34%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.454); called by muse, mutect2, varscan2
- IGFN1 | c.889G>T p.V297F | Missense Mutation (SNP) | VAF 63/229 reads (28%) | SIFT deleterious (0); PolyPhen possibly damaging (0.802); called by muse, mutect2, varscan2
- IGHV3-53 | c.254G>T p.R85L | Missense Mutation (SNP) | VAF 140/822 reads (17%) | SIFT deleterious, low confidence (0.01); PolyPhen possibly damaging (0.47); called by muse, mutect2, varscan2
- IGHV6-1 | c.196G>T p.G66C | Missense Mutation (SNP) | VAF 105/368 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); called by muse, mutect2, varscan2
- IGSF11 | c.477C>A p.S159R (on ENST00000393775 / NM_001015887.3; = p.S158R on NM_152538.4 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 28/143 reads (20%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.996); called by muse, mutect2, varscan2
- INSM1 | c.1066G>C p.G356R | Missense Mutation (SNP) | VAF 35/142 reads (25%) | SIFT tolerated (0.27); PolyPhen probably damaging (0.932); called by muse, mutect2, varscan2
- INSRR | c.3017A>G p.E1006G | Missense Mutation (SNP) | VAF 113/493 reads (23%) | SIFT tolerated (0.09); PolyPhen benign (0); called by muse, mutect2, varscan2
- ITFG1 | c.1612C>G p.P538A | Missense Mutation (SNP) | VAF 72/269 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- ITLN1 | c.312G>T p.Q104H | Missense Mutation (SNP) | VAF 135/513 reads (26%) | SIFT tolerated (0.05); PolyPhen probably damaging (0.993); called by muse, mutect2, varscan2
- KCNA6 | c.125G>T p.R42L | Missense Mutation (SNP) | VAF 32/102 reads (31%) | SIFT deleterious (0); PolyPhen probably damaging (0.928); called by muse, mutect2, varscan2
- KCNG1 | c.1423G>C p.E475Q | Missense Mutation (SNP) | VAF 92/437 reads (21%) | SIFT tolerated (0.55); PolyPhen benign (0.013); called by muse, mutect2, varscan2
- KCNJ3 | c.895C>A p.L299I | Missense Mutation (SNP) | VAF 65/236 reads (28%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.949); called by muse, mutect2, varscan2
- KIF6 | c.1181A>T p.Q394L | Missense Mutation (SNP) | VAF 54/169 reads (32%) | SIFT deleterious (0.02); PolyPhen benign (0.142); called by muse, mutect2, varscan2
- KLC2 | c.95G>T p.R32L | Missense Mutation (SNP) | VAF 405/816 reads (50%) | SIFT deleterious (0); PolyPhen possibly damaging (0.815); called by muse, mutect2, varscan2
- KMT2B | c.7022G>T p.G2341V | Missense Mutation (SNP) | VAF 104/223 reads (47%) | SIFT tolerated (0.26); PolyPhen benign (0.047); called by muse, mutect2, varscan2
- KRT26 | c.843+1G>T p.X281_splice | Splice Site (SNP) | VAF 79/224 reads (35%) | called by muse, mutect2, varscan2
- LAPTM4B | c.29C>A p.P10Q | Missense Mutation (SNP) | VAF 47/175 reads (27%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.083); called by muse, mutect2, varscan2
- LIG4 | c.2679G>C p.W893C | Missense Mutation (SNP) | VAF 48/169 reads (28%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- LMO7 | c.2686G>C p.V896L (on ENST00000357063; = p.V577L on NM_005358.5) | Missense Mutation (SNP) | VAF 45/169 reads (27%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.906); called by muse, mutect2, varscan2
- LRP1 | c.10411T>G p.W3471G | Missense Mutation (SNP) | VAF 36/165 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); called by muse, mutect2, varscan2
- LRP1B | c.9247G>T p.V3083F | Missense Mutation (SNP) | VAF 25/74 reads (34%) | SIFT deleterious (0); PolyPhen possibly damaging (0.637); called by muse, mutect2, varscan2
- LRP8 | c.1294G>T p.V432L | Missense Mutation (SNP) | VAF 72/235 reads (31%) | SIFT deleterious (0.01); PolyPhen benign (0.01); called by muse, mutect2, varscan2
- LRRC7 | c.4627G>C p.G1543R (on ENST00000651989 / NM_001370785.2; = p.G1463R on NM_001330635.3 and 2 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 26/92 reads (28%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2
- MAGEA11 | c.1041G>T p.R347S | Missense Mutation (SNP) | VAF 55/181 reads (30%) | SIFT tolerated (0.07); PolyPhen benign (0.243); called by muse, mutect2, varscan2
- MAGEB1 | c.185A>G p.Q62R | Missense Mutation (SNP) | VAF 38/150 reads (25%) | SIFT tolerated (0.11); PolyPhen probably damaging (0.992); called by muse, mutect2, varscan2
- MAGEB18 | c.962G>A p.R321K | Missense Mutation (SNP) | VAF 38/150 reads (25%) | SIFT tolerated (0.32); PolyPhen benign (0.021); called by muse, mutect2, varscan2
- MAP3K15 | c.2141G>A p.G714D | Missense Mutation (SNP) | VAF 60/246 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- MAP3K15 | c.2140G>T p.G714C | Missense Mutation (SNP) | VAF 56/241 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, varscan2
- MAPKBP1 | c.3826G>C p.A1276P (on ENST00000456763 / NM_001128608.2; = p.A1270P on NM_014994.3) | Missense Mutation (SNP) | VAF 94/327 reads (29%) | SIFT tolerated (0.32); PolyPhen possibly damaging (0.529); called by muse, mutect2, varscan2
- MCTP1 | c.2475G>T p.M825I | Missense Mutation (SNP) | VAF 101/267 reads (38%) | SIFT deleterious (0); PolyPhen probably damaging (0.914); called by muse, mutect2, varscan2
- MGAT4C | c.1078G>T p.A360S | Missense Mutation (SNP) | VAF 46/203 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (0.983); called by muse, mutect2, varscan2
- MGAT4C | c.1077G>T p.K359N | Missense Mutation (SNP) | VAF 45/206 reads (22%) | SIFT tolerated (0.23); PolyPhen benign (0.172); called by muse, mutect2, varscan2
- MMP16 | c.619G>C p.A207P | Missense Mutation (SNP) | VAF 69/324 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); called by muse, mutect2, varscan2
- MRC1 | c.1634G>T p.R545I | Missense Mutation (SNP) | VAF 63/197 reads (32%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.984); called by muse, mutect2, varscan2
- MUC16 | c.40306T>C p.Y13436H | Missense Mutation (SNP) | VAF 38/152 reads (25%) | SIFT deleterious, low confidence (0.01); PolyPhen probably damaging (0.989); called by muse, mutect2, varscan2
- MUC16 | c.19869G>T p.M6623I | Missense Mutation (SNP) | VAF 69/274 reads (25%) | SIFT tolerated, low confidence (0.3); PolyPhen benign (0); called by muse, mutect2, varscan2
- MUC16 | c.10172A>T p.E3391V | Missense Mutation (SNP) | VAF 70/234 reads (30%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.015); called by muse, mutect2
- MUC16 | c.4102C>A p.P1368T | Missense Mutation (SNP) | VAF 63/210 reads (30%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.01); called by muse, mutect2, varscan2
- MUC16 | c.2045C>A p.T682K | Missense Mutation (SNP) | VAF 108/415 reads (26%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.01); called by muse, mutect2, varscan2
- MUC5AC | c.14807A>G p.Y4936C | Missense Mutation (SNP) | VAF 109/491 reads (22%) | SIFT tolerated (0.12); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- MYT1L | c.2548G>C p.E850Q | Missense Mutation (SNP) | VAF 93/382 reads (24%) | SIFT deleterious (0.01); PolyPhen benign (0.155); called by muse, mutect2, varscan2
- NAV3 | c.6642A>G p.I2214M (on ENST00000397909 / NM_001024383.2; = p.I2192M on NM_014903.6) | Missense Mutation (SNP) | VAF 37/150 reads (25%) | SIFT deleterious (0.05); PolyPhen probably damaging (0.996); called by muse, mutect2, varscan2
- NEUROD4 | c.798G>T p.K266N | Missense Mutation (SNP) | VAF 54/177 reads (31%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- NF1 | c.5657dup p.L1886Ffs*27 (on ENST00000358273 / NM_001042492.3; = p.L1865Ffs*27 on NM_000267.3) | Frame Shift Ins (INS) | VAF 68/242 reads (28%) | called by pindel, varscan2
- NHS | c.4470C>G p.N1490K | Missense Mutation (SNP) | VAF 133/667 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (0.958); called by muse, mutect2, varscan2
- NLRP6 | c.329G>T p.G110V | Missense Mutation (SNP) | VAF 22/52 reads (42%) | SIFT tolerated (0.19); PolyPhen benign (0.007); called by muse, mutect2, varscan2
- NPAS3 | c.118T>A p.Y40N | Missense Mutation (SNP) | VAF 74/279 reads (27%) | SIFT deleterious, low confidence (0.01); PolyPhen probably damaging (0.969); called by muse, mutect2, varscan2
- NRXN2 | c.4031C>A p.P1344Q | Missense Mutation (SNP) | VAF 218/1131 reads (19%) | SIFT deleterious (0); PolyPhen benign (0.351); called by muse, mutect2, varscan2
- OAS2 | c.554A>C p.Q185P | Missense Mutation (SNP) | VAF 42/194 reads (22%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.924); called by muse, mutect2, varscan2
- OLFM1 | c.484A>T p.R162W (on ENST00000371793 / NM_001282611.2; = p.R144W on NM_014279.5) | Missense Mutation (SNP) | VAF 78/277 reads (28%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.993); called by muse, mutect2
- OPLAH | c.2956_2959del p.S986Kfs*18 | Frame Shift Del (DEL) | VAF 81/394 reads (21%) | called by mutect2, pindel, varscan2
- OR10A6 | c.358T>A p.Y120N | Missense Mutation (SNP) | VAF 80/398 reads (20%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.878); called by muse, mutect2
- OR10D3 | c.439G>T p.G147C | Missense Mutation (SNP) | VAF 98/322 reads (30%) | SIFT deleterious (0.02); PolyPhen benign (0.286); called by muse, mutect2, varscan2
- OR10K1 | c.270G>C p.K90N | Missense Mutation (SNP) | VAF 113/503 reads (22%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.701); called by muse, mutect2, varscan2
- OR2A2 | c.535G>T p.E179* | Nonsense Mutation (SNP) | VAF 29/405 reads (7%) | called by muse, mutect2
- OR2C3 | c.602A>G p.Y201C | Missense Mutation (SNP) | VAF 62/233 reads (27%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.823); called by muse, mutect2, varscan2
- OR2L5 | c.167C>A p.T56K | Missense Mutation (SNP) | VAF 118/459 reads (26%) | SIFT deleterious (0.04); PolyPhen benign (0.012); called by muse, mutect2, varscan2
- OR4C12 | c.636G>T p.L212F | Missense Mutation (SNP) | VAF 36/137 reads (26%) | SIFT deleterious, low confidence (0.01); PolyPhen probably damaging (0.923); called by muse, mutect2, varscan2
- OR4S1 | c.180C>A p.F60L | Missense Mutation (SNP) | VAF 98/334 reads (29%) | SIFT deleterious (0.01); PolyPhen benign (0.39); called by muse, mutect2, varscan2
- OR51I2 | c.239C>T p.T80I | Missense Mutation (SNP) | VAF 36/138 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (0.991); called by muse, mutect2, varscan2
- OR52B6 | c.440C>A p.S147Y | Missense Mutation (SNP) | VAF 23/96 reads (24%) | SIFT tolerated (1); PolyPhen benign (0); called by muse, mutect2, varscan2
- OR56A3 | c.482T>C p.L161P | Missense Mutation (SNP) | VAF 105/368 reads (29%) | SIFT deleterious (0); PolyPhen possibly damaging (0.653); called by muse, mutect2, varscan2
- OR5M8 | c.413G>T p.S138I | Missense Mutation (SNP) | VAF 99/395 reads (25%) | SIFT tolerated (0.16); PolyPhen benign (0.009); called by muse, mutect2, varscan2
- OR6N2 | c.859C>A p.P287T | Missense Mutation (SNP) | VAF 57/203 reads (28%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); called by muse, mutect2, varscan2
- OR6Q1 | c.871C>A p.P291T | Missense Mutation (SNP) | VAF 83/250 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); called by muse, mutect2, varscan2
- OR6V1 | c.254del p.V85Afs*29 | Frame Shift Del (DEL) | VAF 157/334 reads (47%) | called by mutect2, pindel, varscan2
- OR9I1 | c.148C>T p.Q50* | Nonsense Mutation (SNP) | VAF 20/129 reads (16%) | called by muse, mutect2, varscan2
- OTOG | c.2638C>A p.P880T | Missense Mutation (SNP) | VAF 30/157 reads (19%) | SIFT tolerated (1); PolyPhen probably damaging (0.992); called by muse, varscan2
- OTOP1 | c.113C>A p.S38Y | Missense Mutation (SNP) | VAF 19/103 reads (18%) | SIFT deleterious, low confidence (0.03); PolyPhen benign (0.099); called by muse, varscan2
- OVCH1 | c.1201A>T p.S401C | Missense Mutation (SNP) | VAF 109/430 reads (25%) | SIFT tolerated (0.08); PolyPhen benign (0.029); called by muse, mutect2, varscan2
- PABPC1 | c.185C>T p.P62L | Missense Mutation (SNP) | VAF 88/296 reads (30%) | SIFT tolerated (0.07); PolyPhen possibly damaging (0.652); called by muse, mutect2, varscan2
- PAX1 | c.160G>T p.G54C | Missense Mutation (SNP) | VAF 103/412 reads (25%) | SIFT tolerated, low confidence (0.13); PolyPhen benign (0.007); called by muse, mutect2, varscan2
- PCDH15 | c.5848A>T p.S1950C | Missense Mutation (SNP) | VAF 18/88 reads (20%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.635); called by muse, mutect2, varscan2
- PCDH15 | c.3130C>A p.P1044T | Missense Mutation (SNP) | VAF 109/454 reads (24%) | SIFT tolerated (0.07); PolyPhen benign (0.241); called by muse, mutect2, varscan2
- PCDH9 | c.2308G>T p.V770L | Missense Mutation (SNP) | VAF 37/175 reads (21%) | SIFT tolerated (0.12); PolyPhen possibly damaging (0.524); called by muse, mutect2, varscan2
- PDE6C | c.1683C>A p.Y561* | Nonsense Mutation (SNP) | VAF 167/659 reads (25%) | called by muse, mutect2, varscan2
- PEAK3 | c.61C>A p.Q21K | Missense Mutation (SNP) | VAF 30/119 reads (25%) | SIFT tolerated (0.05); PolyPhen benign (0.115); called by muse, mutect2, varscan2
- PGR | c.532A>G p.T178A | Missense Mutation (SNP) | VAF 73/302 reads (24%) | SIFT tolerated, low confidence (0.3); PolyPhen benign (0.184); called by muse, mutect2, varscan2
- PHEX | c.746T>G p.L249R | Missense Mutation (SNP) | VAF 115/485 reads (24%) | SIFT deleterious (0); PolyPhen possibly damaging (0.828); called by muse, mutect2, varscan2
- PHF20 | c.2500T>C p.Y834H | Missense Mutation (SNP) | VAF 48/198 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); called by muse, mutect2, varscan2
- PIM3 | c.443G>C p.R148P | Missense Mutation (SNP) | VAF 174/681 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (0.982); called by muse, mutect2, varscan2
- PKHD1L1 | c.2988G>C p.Q996H | Missense Mutation (SNP) | VAF 81/368 reads (22%) | SIFT deleterious (0); PolyPhen possibly damaging (0.712); called by muse, mutect2, varscan2
- PLEKHA7 | c.2909G>T p.G970V | Missense Mutation (SNP) | VAF 160/518 reads (31%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- PLPPR5 | c.513C>G p.I171M | Missense Mutation (SNP) | VAF 161/662 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (0.985); called by muse, mutect2, varscan2
- PLSCR2 | c.186A>T p.Q62H | Missense Mutation (SNP) | VAF 234/581 reads (40%) | SIFT tolerated (0.14); PolyPhen benign (0.195); called by muse, mutect2, varscan2
- PLXNB2 | c.4879dup p.S1627Ffs*47 | Frame Shift Ins (INS) | VAF 42/192 reads (22%) | called by mutect2, pindel, varscan2
- PNN | c.2063A>T p.K688M | Missense Mutation (SNP) | VAF 47/195 reads (24%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- PPEF1 | c.1623G>A p.M541I | Missense Mutation (SNP) | VAF 16/62 reads (26%) | SIFT tolerated (0.22); PolyPhen benign (0.079); called by muse, mutect2, varscan2
- PPM1E | c.1777G>A p.G593S | Missense Mutation (SNP) | VAF 88/261 reads (34%) | SIFT tolerated, low confidence (0.58); PolyPhen benign (0.027); called by muse, mutect2, varscan2
- PPP1R2C | c.24C>A p.H8Q | Missense Mutation (SNP) | VAF 30/120 reads (25%) | SIFT tolerated (0.33); PolyPhen benign (0.007); called by muse, mutect2, varscan2
- PPP1R9A | c.1214G>T p.R405M | Missense Mutation (SNP) | VAF 96/222 reads (43%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.994); called by muse, mutect2, varscan2
- PPP4R3C | c.758C>A p.P253Q | Missense Mutation (SNP) | VAF 79/336 reads (24%) | SIFT deleterious (0.01); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- PPTC7 | c.104G>T p.G35V | Missense Mutation (SNP) | VAF 216/790 reads (27%) | SIFT tolerated (0.5); PolyPhen benign (0.028); called by muse, mutect2, varscan2
- PRCC | c.1390-2A>T p.X464_splice | Splice Site (SNP) | VAF 87/253 reads (34%) | called by muse, mutect2, varscan2
- PRSS56 | c.1123G>C p.G375R | Missense Mutation (SNP) | VAF 76/263 reads (29%) | SIFT tolerated (0.12); PolyPhen benign (0.209); called by muse, mutect2, varscan2
- PTPN22 | c.1190G>T p.W397L (on ENST00000359785 / NM_001193431.2; = p.W342L on NM_012411.5) | Missense Mutation (SNP) | VAF 86/299 reads (29%) | SIFT tolerated (0.07); PolyPhen benign (0.049); called by muse, mutect2, varscan2
- PWP1 | c.451C>G p.L151V | Missense Mutation (SNP) | VAF 23/135 reads (17%) | SIFT deleterious (0); PolyPhen benign (0.266); called by muse, mutect2, varscan2
- RAPGEF6 | c.2167G>T p.G723* | Nonsense Mutation (SNP) | VAF 104/273 reads (38%) | called by muse, mutect2, varscan2
- RASSF9 | c.392C>T p.A131V | Missense Mutation (SNP) | VAF 56/219 reads (26%) | SIFT deleterious (0.02); PolyPhen benign (0.099); called by muse, mutect2, varscan2
- REPS2 | c.64G>A p.G22S | Missense Mutation (SNP) | VAF 28/59 reads (47%) | SIFT tolerated, low confidence (0.08); PolyPhen probably damaging (0.986); called by muse, mutect2, varscan2
- RET | c.2839C>A p.L947I | Missense Mutation (SNP) | VAF 277/1058 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- RGPD3 | c.3467T>C p.L1156P | Missense Mutation (SNP) | VAF 256/1193 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (0.986); called by muse, mutect2, varscan2
- RHCG | c.1089C>A p.S363R | Missense Mutation (SNP) | VAF 93/322 reads (29%) | SIFT deleterious (0.05); PolyPhen benign (0.088); called by muse, mutect2, varscan2
- RNASET2 | c.608dup p.T204Hfs*2 | Frame Shift Ins (INS) | VAF 93/419 reads (22%) | called by mutect2, pindel, varscan2
- ROS1 | c.5719G>T p.A1907S | Missense Mutation (SNP) | VAF 79/401 reads (20%) | SIFT tolerated (0.06); PolyPhen probably damaging (0.957); called by muse, mutect2, varscan2
- RP1 | c.2386G>T p.G796C | Missense Mutation (SNP) | VAF 51/196 reads (26%) | SIFT deleterious (0.03); PolyPhen benign (0.003); called by muse, mutect2, varscan2
- RTF1 | c.1106T>C p.L369P | Missense Mutation (SNP) | VAF 63/225 reads (28%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); called by muse, mutect2, varscan2
- RTL9 | c.2825C>A p.T942K | Missense Mutation (SNP) | VAF 114/303 reads (38%) | SIFT tolerated (0.16); PolyPhen benign (0.124); called by muse, mutect2, varscan2
- RYR1 | c.11384C>A p.S3795Y | Missense Mutation (SNP) | VAF 109/817 reads (13%) | SIFT tolerated (0.08); PolyPhen possibly damaging (0.687); called by muse, mutect2, varscan2
- RYR2 | c.3680T>A p.F1227Y | Missense Mutation (SNP) | VAF 121/491 reads (25%) | SIFT tolerated (0.33); PolyPhen benign (0.015); called by muse, mutect2, varscan2
- SAMD1 | c.143G>A p.R48Q | Missense Mutation (SNP) | VAF 97/357 reads (27%) | SIFT deleterious (0); PolyPhen benign (0.134); called by muse, mutect2, varscan2
- SCN3A | c.1640C>A p.T547N | Missense Mutation (SNP) | VAF 85/290 reads (29%) | SIFT tolerated (0.39); PolyPhen benign (0.011); called by muse, mutect2, varscan2
- SDC3 | c.918G>T p.E306D | Missense Mutation (SNP) | VAF 63/234 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (0.992); called by muse, mutect2, varscan2
- SEC16A | c.4524G>T p.K1508N | Missense Mutation (SNP) | VAF 58/171 reads (34%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- SEC23B | c.1224G>T p.L408F | Missense Mutation (SNP) | VAF 45/295 reads (15%) | SIFT tolerated (0.46); PolyPhen benign (0.208); called by muse, mutect2, varscan2
- SERPINA5 | c.518A>T p.N173I | Missense Mutation (SNP) | VAF 114/386 reads (30%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- SEZ6L | c.1787C>A p.P596H | Missense Mutation (SNP) | VAF 108/470 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- SF3B2 | c.1742A>T p.K581M | Missense Mutation (SNP) | VAF 76/446 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- SKAP1 | c.122T>C p.I41T | Missense Mutation (SNP) | VAF 91/235 reads (39%) | SIFT deleterious (0); PolyPhen probably damaging (0.991); called by muse, mutect2, varscan2
- SKOR1 | c.211G>A p.A71T | Missense Mutation (SNP) | VAF 18/50 reads (36%) | SIFT tolerated (0.38); PolyPhen benign (0.003); called by muse, mutect2, varscan2
- SLC10A2 | c.406C>A p.L136I | Missense Mutation (SNP) | VAF 143/563 reads (25%) | SIFT tolerated (0.07); PolyPhen possibly damaging (0.53); called by muse, mutect2, varscan2
- SLC12A3 | c.193C>G p.P65A | Missense Mutation (SNP) | VAF 201/750 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2
- SLC18A2 | c.1159C>G p.P387A | Missense Mutation (SNP) | VAF 13/31 reads (42%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- SLC22A16 | c.1247C>G p.T416R | Missense Mutation (SNP) | VAF 82/288 reads (28%) | SIFT tolerated (0.07); PolyPhen benign (0.089); called by muse, mutect2, varscan2
- SLC39A12 | c.719C>A p.S240Y | Missense Mutation (SNP) | VAF 85/278 reads (31%) | SIFT tolerated (0.46); PolyPhen possibly damaging (0.494); called by muse, mutect2, varscan2
- SLC4A9 | c.664C>A p.P222T (on ENST00000507527 / NM_001258428.2; = p.P198T on NM_031467.3) | Missense Mutation (SNP) | VAF 57/155 reads (37%) | SIFT tolerated (0.17); PolyPhen possibly damaging (0.557); called by muse, varscan2
- SLC4A9 | c.665C>G p.P222R (on ENST00000507527 / NM_001258428.2; = p.P198R on NM_031467.3) | Missense Mutation (SNP) | VAF 57/154 reads (37%) | SIFT tolerated (0.49); PolyPhen possibly damaging (0.858); called by muse, varscan2
- SLC5A12 | c.1830T>A p.N610K | Missense Mutation (SNP) | VAF 33/120 reads (28%) | SIFT deleterious, low confidence (0.02); PolyPhen benign (0.003); called by muse, mutect2, varscan2
- SLCO5A1 | c.1349C>A p.A450D | Missense Mutation (SNP) | VAF 51/187 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (0.989); called by muse, mutect2, varscan2
- SP8 | c.1285G>T p.D429Y (on ENST00000361443 / NM_198956.4; = p.D447Y on NM_182700.6) | Missense Mutation (SNP) | VAF 228/869 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, varscan2
- SPACA7 | c.3G>T p.M1? | Translation Start Site (SNP) | VAF 76/266 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (0.986); called by muse, mutect2, varscan2
- SPATA31D4 | c.2506G>T p.E836* | Nonsense Mutation (SNP) | VAF 78/456 reads (17%) | called by mutect2, varscan2
- SPATA5L1 | c.2255G>T p.G752V | Missense Mutation (SNP) | VAF 28/99 reads (28%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.015); called by muse, mutect2, varscan2
- SPOCK1 | c.207G>T p.W69C | Missense Mutation (SNP) | VAF 27/104 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (0.977); called by muse, mutect2, varscan2
- SPRED2 | c.471G>T p.Q157H | Missense Mutation (SNP) | VAF 58/316 reads (18%) | SIFT tolerated (0.14); PolyPhen benign (0.326); called by mutect2, varscan2
- SPRED2 | c.445_468del p.T149_S156del | In Frame Del (DEL) | VAF 74/347 reads (21%) | called by mutect2, pindel
- SRGAP2 | c.3035G>T p.S1012I (on ENST00000624873 / NM_001170637.4; = p.S1013I on NM_015326.5 and 2 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 58/220 reads (26%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.957); called by muse, mutect2, varscan2
- STAB2 | c.3186C>A p.Y1062* | Nonsense Mutation (SNP) | VAF 28/106 reads (26%) | called by muse, mutect2, varscan2
- STAB2 | c.3187C>A p.H1063N | Missense Mutation (SNP) | VAF 28/107 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); called by muse, mutect2, varscan2
- STK38L | c.327_329del p.K110del | In Frame Del (DEL) | VAF 32/166 reads (19%) | called by pindel, varscan2
- STON2 | c.367G>A p.E123K | Missense Mutation (SNP) | VAF 60/198 reads (30%) | SIFT tolerated, low confidence (0.79); PolyPhen possibly damaging (0.615); called by muse, mutect2, varscan2
- STYXL2 | c.204A>T p.E68D | Missense Mutation (SNP) | VAF 69/226 reads (31%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.991); called by muse, mutect2, varscan2
- SWT1 | c.1015G>T p.A339S | Missense Mutation (SNP) | VAF 41/171 reads (24%) | SIFT tolerated (0.1); PolyPhen benign (0.003); called by muse, mutect2, varscan2
- TAF6 | c.188G>A p.R63Q | Missense Mutation (SNP) | VAF 53/172 reads (31%) | SIFT deleterious (0); PolyPhen probably damaging (0.97); called by muse, mutect2, varscan2
- TBK1 | c.1824G>T p.K608N | Missense Mutation (SNP) | VAF 20/74 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (0.987); called by muse, mutect2, varscan2
- TEX13A | c.1117G>T p.V373L | Missense Mutation (SNP) | VAF 14/374 reads (4%) | SIFT tolerated (0.2); PolyPhen benign (0.001); called by muse, mutect2
- THBS2 | c.2947C>G p.H983D | Missense Mutation (SNP) | VAF 83/311 reads (27%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.852); called by muse, mutect2, varscan2
- THOP1 | c.1489G>T p.E497* | Nonsense Mutation (SNP) | VAF 94/348 reads (27%) | called by muse, mutect2, varscan2
- TLL2 | c.1362G>T p.K454N | Missense Mutation (SNP) | VAF 80/284 reads (28%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.99); called by muse, mutect2, varscan2
- TLR10 | c.532C>A p.P178T | Missense Mutation (SNP) | VAF 15/88 reads (17%) | SIFT tolerated (0.21); PolyPhen benign (0); called by muse, mutect2, varscan2
- TLR4 | c.892G>C p.D298H (on ENST00000355622 / NM_138554.5; = p.D258H on NM_003266.4) | Missense Mutation (SNP) | VAF 81/316 reads (26%) | SIFT deleterious (0.04); PolyPhen benign (0.247); called by muse, mutect2, varscan2
- TMEM266 | c.682G>T p.E228* | Nonsense Mutation (SNP) | VAF 81/268 reads (30%) | called by muse, mutect2, varscan2
- TMPRSS15 | c.2118C>G p.N706K | Missense Mutation (SNP) | VAF 115/306 reads (38%) | SIFT deleterious (0.05); PolyPhen possibly damaging (0.725); called by muse, mutect2, varscan2
- TMPRSS6 | c.1840A>T p.S614C | Missense Mutation (SNP) | VAF 50/218 reads (23%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.961); called by muse, mutect2, varscan2
- TOGARAM2 | c.617A>G p.E206G | Missense Mutation (SNP) | VAF 80/281 reads (28%) | SIFT tolerated (0.15); PolyPhen benign (0.001); called by muse, mutect2, varscan2
- TRA2B | c.37-1G>T p.X13_splice | Splice Site (SNP) | VAF 139/280 reads (50%) | called by muse, mutect2, varscan2
- TRIM51 | c.477C>G p.N159K | Missense Mutation (SNP) | VAF 37/201 reads (18%) | SIFT tolerated (0.17); PolyPhen benign (0.01); called by muse, mutect2, varscan2
- TRIM64B | c.890G>T p.C297F | Missense Mutation (SNP) | VAF 44/263 reads (17%) | SIFT tolerated (0.7); PolyPhen benign (0.174); called by mutect2, varscan2
- TRIM67 | c.1186G>T p.A396S | Missense Mutation (SNP) | VAF 100/445 reads (22%) | SIFT tolerated (0.25); PolyPhen benign (0.028); called by muse, mutect2, varscan2
- TRMU | c.1234G>T p.E412* | Nonsense Mutation (SNP) | VAF 181/683 reads (27%) | called by muse, mutect2, varscan2
- TSPAN18 | c.329A>T p.E110V | Missense Mutation (SNP) | VAF 38/152 reads (25%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.91); called by muse, mutect2, varscan2
- TTYH3 | c.1167C>G p.I389M | Missense Mutation (SNP) | VAF 89/415 reads (21%) | SIFT deleterious (0); PolyPhen possibly damaging (0.844); called by muse, mutect2, varscan2
- TXNDC9 | c.332T>A p.L111Q | Missense Mutation (SNP) | VAF 37/135 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); called by muse, mutect2, varscan2
- UBE3A | c.1735G>T p.V579L | Missense Mutation (SNP) | VAF 54/270 reads (20%) | SIFT tolerated (0.17); PolyPhen benign (0.027); called by muse, mutect2, varscan2
- UBR5 | c.1540A>T p.K514* | Nonsense Mutation (SNP) | VAF 47/178 reads (26%) | called by muse, mutect2, varscan2
- UNC80 | c.1816C>G p.P606A | Missense Mutation (SNP) | VAF 159/641 reads (25%) | SIFT deleterious, low confidence (0.03); PolyPhen probably damaging (0.996); called by muse, mutect2, varscan2
- USP27X | c.644C>T p.A215V | Missense Mutation (SNP) | VAF 50/263 reads (19%) | SIFT tolerated (0.61); PolyPhen benign (0.013); called by muse, mutect2, varscan2
- USP34 | c.4624G>T p.A1542S | Missense Mutation (SNP) | VAF 109/469 reads (23%) | SIFT tolerated (0.19); PolyPhen probably damaging (0.935); called by muse, mutect2, varscan2
- UST | c.491T>C p.L164S | Missense Mutation (SNP) | VAF 24/118 reads (20%) | SIFT deleterious (0); PolyPhen benign (0.374); called by muse, mutect2, varscan2
- WASHC4 | c.1390A>T p.M464L | Missense Mutation (SNP) | VAF 26/147 reads (18%) | SIFT tolerated (1); PolyPhen benign (0); called by muse, mutect2, varscan2
- WDR72 | c.650C>T p.T217I | Missense Mutation (SNP) | VAF 61/248 reads (25%) | SIFT deleterious (0.01); PolyPhen benign (0.157); called by muse, mutect2, varscan2
- WEE1 | c.836G>T p.R279I | Missense Mutation (SNP) | VAF 35/126 reads (28%) | SIFT tolerated (0.29); PolyPhen benign (0.028); called by muse, mutect2, varscan2
- WEE2 | c.337C>A p.P113T | Missense Mutation (SNP) | VAF 45/81 reads (56%) | SIFT deleterious (0); PolyPhen probably damaging (0.931); called by muse, mutect2, varscan2
- XYLT1 | c.835G>T p.E279* | Nonsense Mutation (SNP) | VAF 6/24 reads (25%) | called by muse, mutect2, varscan2
- ZCCHC9 | c.485C>T p.S162F | Missense Mutation (SNP) | VAF 71/222 reads (32%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); called by muse, mutect2, varscan2
- ZDBF2 | c.394T>A p.S132T | Missense Mutation (SNP) | VAF 67/232 reads (29%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.517); called by muse, mutect2, varscan2
- ZFPM2 | c.238G>T p.G80W | Missense Mutation (SNP) | VAF 114/360 reads (32%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.808); called by muse, mutect2, varscan2
- ZFR2 | c.2433+1G>A p.X811_splice | Splice Site (SNP) | VAF 89/298 reads (30%) | called by muse, mutect2, varscan2
- ZNF263 | c.838A>T p.S280C | Missense Mutation (SNP) | VAF 55/246 reads (22%) | SIFT deleterious (0.02); PolyPhen benign (0.319); called by muse, mutect2, varscan2
- ZNF311 | c.1696C>G p.H566D | Missense Mutation (SNP) | VAF 110/344 reads (32%) | SIFT tolerated (0.06); PolyPhen benign (0.142); called by muse, mutect2, varscan2
- ZNF529 | c.950A>T p.K317M | Missense Mutation (SNP) | VAF 12/96 reads (13%) | SIFT tolerated (0.05); PolyPhen probably damaging (0.992); called by muse, mutect2
- ZNF536 | c.505C>A p.Q169K | Missense Mutation (SNP) | VAF 125/531 reads (24%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.994); called by muse, mutect2, varscan2
- AC011462.1 | c.790A>C p.R264= | Silent (SNP) | VAF 356/742 reads (48%) | called by muse, mutect2, varscan2
- ACTC1 | c.75C>T p.G25= | Silent (SNP) | VAF 90/307 reads (29%) | catalogued as rs144819872, COSV51759615; called by muse, mutect2, varscan2
- AGBL2 | c.1782A>T p.P594= | Silent (SNP) | VAF 25/106 reads (24%) | called by muse, mutect2, varscan2
- AGPAT3 | c.243G>T p.T81= | Silent (SNP) | VAF 83/243 reads (34%) | called by muse, mutect2, varscan2
- ANGPTL3 | c.921G>A p.G307= | Silent (SNP) | VAF 70/344 reads (20%) | called by muse, mutect2, varscan2
- ANKUB1 | c.1332A>G p.T444= | Silent (SNP) | VAF 47/196 reads (24%) | catalogued as COSV67167808; called by muse, mutect2, varscan2
- AP002512.3 | c.1038C>A p.S346= | Silent (SNP) | VAF 52/185 reads (28%) | catalogued as COSV54405556; called by muse, mutect2, varscan2
- ATL2 | c.285A>G p.V95= | Silent (SNP) | VAF 40/164 reads (24%) | catalogued as rs1458889994; called by muse, mutect2, varscan2
- BAAT | c.915G>T p.G305= | Silent (SNP) | VAF 130/737 reads (18%) | called by muse, mutect2, varscan2
- BMP6 | c.1143A>T p.R381= | Silent (SNP) | VAF 188/532 reads (35%) | called by muse, mutect2, varscan2
- BRIX1 | c.771T>G p.P257= | Silent (SNP) | VAF 30/156 reads (19%) | called by muse, mutect2, varscan2
- C1orf167 | c.1986C>T p.A662= | Silent (SNP) | VAF 110/372 reads (30%) | called by muse, mutect2, varscan2
- CD109 | c.3924G>T p.P1308= | Silent (SNP) | VAF 71/387 reads (18%) | catalogued as rs888472256; called by muse, mutect2, varscan2
- CD1A | c.291A>T p.G97= | Silent (SNP) | VAF 62/192 reads (32%) | called by muse, mutect2, varscan2
- CDC14C | c.1191C>T p.R397= (on ENST00000428251; = p.R290= on NM_152627.3) | Silent (SNP) | VAF 66/357 reads (18%) | called by muse, mutect2, varscan2
- CER1 | c.33C>G p.L11= | Silent (SNP) | VAF 35/95 reads (37%) | catalogued as COSV66603791, COSV66604003; called by muse, mutect2, varscan2
- CHD4 | c.2862C>T p.P954= (on ENST00000357008 / NM_001363606.2; = p.P967= on NM_001273.5) | Silent (SNP) | VAF 38/147 reads (26%) | called by muse, mutect2, varscan2
- CLEC14A | c.331C>A p.R111= | Silent (SNP) | VAF 136/500 reads (27%) | catalogued as COSV60564131; called by muse, mutect2, varscan2
- CRYBA4 | c.252G>T p.T84= | Silent (SNP) | VAF 56/208 reads (27%) | called by muse, mutect2, varscan2
- CTNNA2 | c.628C>A p.R210= | Silent (SNP) | VAF 85/334 reads (25%) | catalogued as rs1282303305; called by muse, mutect2, varscan2
- CTU1 | c.909G>A p.A303= | Silent (SNP) | VAF 66/108 reads (61%) | catalogued as rs757161423; called by muse, mutect2, varscan2
- CYP11B1 | c.165C>A p.I55= | Silent (SNP) | VAF 252/1051 reads (24%) | catalogued as rs748324186; called by mutect2, varscan2
- DNER | c.1341G>C p.V447= | Silent (SNP) | VAF 149/703 reads (21%) | called by muse, mutect2, varscan2
- DNMT3B | c.594G>T p.G198= | Silent (SNP) | VAF 121/418 reads (29%) | called by muse, mutect2, varscan2
- DOCK10 | c.4779G>A p.K1593= | Silent (SNP) | VAF 39/134 reads (29%) | called by muse, mutect2, varscan2
- DOCK6 | c.1998C>G p.R666= | Silent (SNP) | VAF 55/195 reads (28%) | called by muse, mutect2, varscan2
- ELAVL4 | c.585C>A p.G195= | Silent (SNP) | VAF 97/569 reads (17%) | called by muse, mutect2, varscan2
- EMILIN1 | c.378C>T p.G126= | Silent (SNP) | VAF 141/508 reads (28%) | catalogued as rs937788712; called by muse, mutect2, varscan2
- EMILIN2 | c.1689G>A p.G563= | Silent (SNP) | VAF 46/165 reads (28%) | called by muse, mutect2, varscan2
- ERN2 | c.543C>A p.T181= | Silent (SNP) | VAF 59/176 reads (34%) | catalogued as COSV56834073; called by muse, mutect2, varscan2
- F11 | c.975C>A p.V325= | Silent (SNP) | VAF 133/350 reads (38%) | called by muse, mutect2, varscan2
- FAM168B | c.210G>T p.V70= | Silent (SNP) | VAF 63/197 reads (32%) | called by muse, mutect2, varscan2
- FAM178B | c.1909C>A p.R637= (on ENST00000490605 / NM_001122646.3; = p.R77= on NM_016490.4 and 1 other RefSeq transcript) | Silent (SNP) | VAF 102/321 reads (32%) | called by muse, mutect2, varscan2
- FN3KRP | c.255G>C p.V85= | Silent (SNP) | VAF 70/167 reads (42%) | catalogued as rs758868078; called by muse, mutect2, varscan2
- GALNT14 | c.664C>A p.R222= | Silent (SNP) | VAF 79/331 reads (24%) | catalogued as COSV100204423; called by muse, mutect2, varscan2
- GDF10 | c.492G>T p.L164= | Silent (SNP) | VAF 65/298 reads (22%) | called by muse, mutect2, varscan2
- GPR180 | c.12G>T p.L4= | Silent (SNP) | VAF 65/253 reads (26%) | called by muse, mutect2, varscan2
- GPRIN2 | c.597A>G p.L199= | Silent (SNP) | VAF 19/136 reads (14%) | called by muse, mutect2, varscan2
- GPSM1 | c.285G>T p.L95= | Silent (SNP) | VAF 77/257 reads (30%) | called by muse, mutect2, varscan2
- GRIPAP1 | c.1395G>T p.V465= | Silent (SNP) | VAF 134/575 reads (23%) | called by muse, mutect2, varscan2
- HABP2 | c.966G>A p.A322= | Silent (SNP) | VAF 91/428 reads (21%) | catalogued as rs569670909; called by muse, mutect2
- IQCF6 | c.213C>A p.I71= | Silent (SNP) | VAF 79/209 reads (38%) | called by muse, mutect2, varscan2
- IQSEC3 | c.1027C>T p.L343= (on ENST00000538872 / NM_001170738.2; = p.L40= on NM_015232.1) | Silent (SNP) | VAF 86/345 reads (25%) | catalogued as COSV58283931; called by muse, mutect2, varscan2
- ISL1 | c.846G>T p.V282= | Silent (SNP) | VAF 93/468 reads (20%) | called by muse, mutect2, varscan2
- ITGA8 | c.783C>T p.S261= | Silent (SNP) | VAF 45/190 reads (24%) | called by muse, mutect2, varscan2
- JPH4 | c.1608C>T p.S536= | Silent (SNP) | VAF 81/311 reads (26%) | catalogued as rs777264708; called by muse, mutect2, varscan2
- JUP | c.1165C>T p.L389= | Silent (SNP) | VAF 51/133 reads (38%) | catalogued as rs1057523570; ClinVar: likely benign; called by muse, mutect2, varscan2
- KCNK16 | c.699G>T p.R233= | Silent (SNP) | VAF 69/183 reads (38%) | called by muse, mutect2, varscan2
- KCNMA1 | c.2776C>T p.L926= (on ENST00000286628 / NM_001161352.2; = p.L868= on NM_002247.4) | Silent (SNP) | VAF 136/444 reads (31%) | called by muse, varscan2
- KCNMA1 | c.2089C>A p.R697= | Silent (SNP) | VAF 93/343 reads (27%) | called by muse, mutect2, varscan2
- KIF5A | c.255T>C p.Y85= | Silent (SNP) | VAF 19/696 reads (3%) | called by muse, mutect2
- L3MBTL2 | c.93T>C p.D31= | Silent (SNP) | VAF 103/379 reads (27%) | catalogued as rs768511706; called by muse, mutect2, varscan2
- LAMA5 | c.156G>A p.L52= | Silent (SNP) | VAF 28/74 reads (38%) | called by muse, mutect2, varscan2
- LCE1E | c.261T>A p.R87= | Silent (SNP) | VAF 105/379 reads (28%) | catalogued as COSV100908551; called by muse, varscan2
- LCE2B | c.183G>A p.G61= | Silent (SNP) | VAF 157/633 reads (25%) | called by muse, mutect2, varscan2
- LY9 | c.681C>A p.P227= | Silent (SNP) | VAF 90/305 reads (30%) | catalogued as COSV54436323, COSV54437902; called by muse, mutect2, varscan2
- MAGEB6B | c.795C>A p.V265= | Silent (SNP) | VAF 93/424 reads (22%) | called by muse, mutect2, varscan2
- MC3R | c.417C>G p.A139= | Silent (SNP) | VAF 93/355 reads (26%) | catalogued as rs753464980; called by muse, mutect2, varscan2
- MCM3AP | c.816G>A p.Q272= | Silent (SNP) | VAF 80/209 reads (38%) | called by muse, mutect2, varscan2
- MIPEP | c.1587G>T p.L529= | Silent (SNP) | VAF 25/107 reads (23%) | called by muse, mutect2, varscan2
- MTHFR | c.1707C>T p.I569= | Silent (SNP) | VAF 90/336 reads (27%) | called by muse, mutect2, varscan2
- MYLK2 | c.237G>A p.E79= | Silent (SNP) | VAF 98/363 reads (27%) | catalogued as rs1370772067, COSV65659456; called by muse, mutect2, varscan2
- MYOM1 | c.2877G>A p.K959= | Silent (SNP) | VAF 46/254 reads (18%) | catalogued as rs755157204; ClinVar: likely benign; called by muse, mutect2
- NCKAP1L | c.2556G>T p.L852= | Silent (SNP) | VAF 110/415 reads (27%) | called by muse, mutect2, varscan2
- NCKAP5L | c.858C>A p.T286= | Silent (SNP) | VAF 58/219 reads (26%) | called by muse, mutect2, varscan2
- NID2 | c.2709T>A p.P903= | Silent (SNP) | VAF 112/402 reads (28%) | catalogued as COSV53504072; called by muse, mutect2, varscan2
- NOL4 | c.1803G>T p.L601= | Silent (SNP) | VAF 47/234 reads (20%) | called by muse, mutect2, varscan2
- NOTCH1 | c.2160C>T p.C720= | Silent (SNP) | VAF 259/879 reads (29%) | called by muse, mutect2, varscan2
- NPHS1 | c.2469G>T p.A823= | Silent (SNP) | VAF 276/599 reads (46%) | called by muse, mutect2, varscan2
- NRXN1 | c.3096T>G p.A1032= | Silent (SNP) | VAF 47/141 reads (33%) | called by muse, mutect2, varscan2
- NTRK3 | c.1788G>A p.Q596= | Silent (SNP) | VAF 107/398 reads (27%) | called by muse, mutect2, varscan2
- NTRK3 | c.1638G>A p.E546= | Silent (SNP) | VAF 196/780 reads (25%) | catalogued as rs960296535; called by muse, mutect2, varscan2
- OAS2 | c.555G>A p.Q185= | Silent (SNP) | VAF 41/193 reads (21%) | called by muse, mutect2, varscan2
- OBSCN | c.9480G>A p.Q3160= | Silent (SNP) | VAF 46/188 reads (24%) | catalogued as COSV52820061; called by muse, varscan2
- OR2M3 | c.561C>G p.L187= | Silent (SNP) | VAF 92/270 reads (34%) | catalogued as COSV101513391; called by muse, mutect2, varscan2
- OR2M7 | c.237C>A p.P79= | Silent (SNP) | VAF 54/212 reads (25%) | catalogued as COSV58739371; called by muse, mutect2, varscan2
- OR4D6 | c.522G>T p.L174= | Silent (SNP) | VAF 54/243 reads (22%) | called by muse, mutect2, varscan2
- OR4K2 | c.366G>A p.R122= | Silent (SNP) | VAF 47/181 reads (26%) | catalogued as rs747735456; called by muse, mutect2, varscan2
- OR5D13 | c.540C>A p.I180= | Silent (SNP) | VAF 38/155 reads (25%) | called by muse, mutect2, varscan2
- OR5K4 | c.69G>C p.L23= | Silent (SNP) | VAF 68/288 reads (24%) | catalogued as COSV61583362; called by muse, mutect2, varscan2
- OR6F1 | c.549C>A p.P183= | Silent (SNP) | VAF 73/320 reads (23%) | called by muse, mutect2, varscan2
- PADI2 | c.1815G>C p.G605= | Silent (SNP) | VAF 123/456 reads (27%) | called by muse, mutect2, varscan2
- PCDH17 | c.1212C>A p.G404= | Silent (SNP) | VAF 101/252 reads (40%) | catalogued as COSV64978302; called by muse, mutect2, varscan2
- PCLO | c.11461C>A p.R3821= | Silent (SNP) | VAF 79/194 reads (41%) | catalogued as COSV100427137; called by muse, mutect2, varscan2
- PON2 | c.1020G>C p.L340= | Silent (SNP) | VAF 51/170 reads (30%) | called by muse, mutect2, varscan2
- PRTFDC1 | c.69G>T p.G23= | Silent (SNP) | VAF 40/220 reads (18%) | called by muse, mutect2, varscan2
- PTH2R | c.1386G>A p.Q462= | Silent (SNP) | VAF 49/188 reads (26%) | catalogued as rs1216389384; called by muse, mutect2, varscan2
- PTPRK | c.1194T>A p.I398= | Silent (SNP) | VAF 38/120 reads (32%) | called by muse, varscan2
- PUM2 | c.1494G>C p.L498= | Silent (SNP) | VAF 83/250 reads (33%) | called by muse, varscan2
- RALGAPA2 | c.5418G>A p.L1806= | Silent (SNP) | VAF 77/296 reads (26%) | called by muse, mutect2, varscan2
- RBM10 | c.1890G>T p.G630= | Silent (SNP) | VAF 105/378 reads (28%) | called by muse, mutect2, varscan2
- RDH10 | c.126C>T p.T42= | Silent (SNP) | VAF 98/354 reads (28%) | catalogued as rs1182353195; called by muse, mutect2, varscan2
- RNF144B | c.876G>T p.R292= | Silent (SNP) | VAF 84/228 reads (37%) | called by muse, mutect2, varscan2
- RPL10L | c.486C>A p.R162= | Silent (SNP) | VAF 91/316 reads (29%) | called by muse, mutect2, varscan2
- SCN1B | c.525G>C p.V175= | Silent (SNP) | VAF 192/921 reads (21%) | called by muse, mutect2, varscan2
- SCP2 | c.336G>T p.V112= | Silent (SNP) | VAF 113/429 reads (26%) | called by muse, mutect2, varscan2
- SFTPA2 | c.273T>A p.A91= | Silent (SNP) | VAF 178/605 reads (29%) | called by muse, mutect2, varscan2
- SLC14A1 | c.498C>A p.S166= | Silent (SNP) | VAF 91/425 reads (21%) | catalogued as COSV58933123; called by muse, mutect2, varscan2
- SLC18A1 | c.147A>G p.L49= | Silent (SNP) | VAF 23/60 reads (38%) | called by muse, mutect2, varscan2
- SLC2A7 | c.102A>T p.S34= | Silent (SNP) | VAF 107/495 reads (22%) | called by muse, mutect2, varscan2
- SLC6A4 | c.1602G>A p.G534= | Silent (SNP) | VAF 98/302 reads (32%) | catalogued as rs1400733667; called by muse, mutect2, varscan2
- SLX4 | c.3777C>A p.A1259= | Silent (SNP) | VAF 93/329 reads (28%) | called by muse, mutect2, varscan2
- SNX20 | c.591G>T p.R197= | Silent (SNP) | VAF 62/223 reads (28%) | catalogued as rs1214770231; called by muse, mutect2, varscan2
- SOX17 | c.678G>T p.P226= | Silent (SNP) | VAF 65/211 reads (31%) | called by muse, mutect2, varscan2
- SPATA31D1 | c.4200T>C p.T1400= | Silent (SNP) | VAF 64/188 reads (34%) | catalogued as rs1345844759; called by muse, mutect2, varscan2
- SYT10 | c.1509C>T p.G503= | Silent (SNP) | VAF 61/300 reads (20%) | catalogued as rs566847178; called by muse, mutect2, varscan2
- SYT16 | c.1908C>A p.I636= | Silent (SNP) | VAF 51/193 reads (26%) | called by muse, mutect2, varscan2
- TAF4 | c.2595G>T p.R865= | Silent (SNP) | VAF 77/301 reads (26%) | catalogued as rs200025111; called by muse, mutect2, varscan2
- TCL1A | c.306C>A p.G102= | Silent (SNP) | VAF 56/268 reads (21%) | catalogued as COSV68085760, COSV68085764; called by muse, varscan2
- TDRD5 | c.1630C>A p.R544= | Silent (SNP) | VAF 101/420 reads (24%) | catalogued as COSV54240128; called by muse, mutect2, varscan2
- THEGL | c.1095G>A p.L365= | Silent (SNP) | VAF 37/115 reads (32%) | called by muse, mutect2, varscan2
- TLL2 | c.351G>A p.K117= | Silent (SNP) | VAF 89/273 reads (33%) | called by muse, mutect2, varscan2
- TMEM114 | c.528C>A p.A176= | Silent (SNP) | VAF 144/525 reads (27%) | catalogued as rs941417178; called by muse, mutect2, varscan2
- TMEM131 | c.1188G>T p.S396= | Silent (SNP) | VAF 20/79 reads (25%) | catalogued as COSV51770489; called by muse, mutect2, varscan2
- TMEM132D | c.2640C>G p.T880= | Silent (SNP) | VAF 219/447 reads (49%) | catalogued as COSV67162373; called by muse, mutect2, varscan2
- TRAV6 | c.378C>T p.T126= | Silent (SNP) | VAF 18/54 reads (33%) | called by muse, mutect2, varscan2
- TTN | c.96576C>A p.V32192= (on ENST00000591111; = p.V24768= on NM_003319.4) | Silent (SNP) | VAF 137/534 reads (26%) | called by muse, mutect2, varscan2
- TTN | c.84462T>C p.Y28154= (on ENST00000591111; = p.Y20730= on NM_003319.4) | Silent (SNP) | VAF 35/183 reads (19%) | catalogued as rs759872462; called by muse, mutect2, varscan2
- TTN | c.25798T>C p.L8600= (on ENST00000591111; = p.L7673= on NM_133378.4 and 1 other RefSeq transcript) | Silent (SNP) | VAF 45/142 reads (32%) | called by muse, mutect2, varscan2
- UBE2QL1 | c.384A>G p.S128= | Silent (SNP) | VAF 82/167 reads (49%) | called by muse, mutect2, varscan2
- UNC13C | c.1026A>T p.L342= | Silent (SNP) | VAF 20/87 reads (23%) | called by muse, mutect2, varscan2
- URGCP | c.1488G>T p.L496= (on ENST00000453200 / NM_001077663.3; = p.L487= on NM_017920.4) | Silent (SNP) | VAF 141/564 reads (25%) | catalogued as rs1434714454; called by muse, mutect2, varscan2
- VAT1L | c.156G>T p.G52= | Silent (SNP) | VAF 74/327 reads (23%) | catalogued as rs971704141; called by muse, mutect2, varscan2
- XPO7 | c.648C>T p.L216= | Silent (SNP) | VAF 46/150 reads (31%) | catalogued as rs934594459, COSV53014251; called by muse, mutect2, varscan2
- ZNF462 | c.417A>C p.S139= | Silent (SNP) | VAF 45/170 reads (26%) | called by muse, mutect2, varscan2
- ZNF492 | c.1176C>A p.P392= | Silent (SNP) | VAF 52/435 reads (12%) | called by muse, mutect2, varscan2
- ZNF80 | c.21G>T p.G7= | Silent (SNP) | VAF 23/71 reads (32%) | called by muse, mutect2, varscan2
- ZNF98 | c.1299C>A p.P433= | Silent (SNP) | VAF 10/40 reads (25%) | called by mutect2, varscan2
- AANAT | c.-4C>T | 5'UTR (SNP) | VAF 358/525 reads (68%) | catalogued as rs1384363902; called by muse, mutect2, varscan2
- AC002519.1 | chr16:31792649 G>A | 3'Flank (SNP) | VAF 34/170 reads (20%) | called by muse, mutect2, varscan2
- AC103796.1 | n.148-24907G>T | Intron (SNP) | VAF 73/401 reads (18%) | called by muse, mutect2, varscan2
- AC116655.1 | n.591G>T | RNA (SNP) | VAF 75/441 reads (17%) | called by muse, mutect2, varscan2
- ACAA2 | chr18:49814408 G>T | 5'Flank (SNP) | VAF 24/71 reads (34%) | called by muse, mutect2, varscan2
- ADAM6 | n.1175G>T | RNA (SNP) | VAF 121/450 reads (27%) | called by muse, mutect2, varscan2
- ADAM6 | n.1174G>T | RNA (SNP) | VAF 122/445 reads (27%) | called by muse, mutect2, varscan2
- ADGRL2 | c.3102-703T>C | Intron (SNP) | VAF 6/16 reads (38%) | called by muse, mutect2
- AGAP12P | n.811G>T | RNA (SNP) | VAF 64/246 reads (26%) | called by mutect2, varscan2
- AL162726.3 | n.255+83427G>T | Intron (SNP) | VAF 119/486 reads (24%) | catalogued as rs369213163; called by muse, mutect2, varscan2
- AL353804.6 | chrX:73826597 C>A | 3'Flank (SNP) | VAF 57/158 reads (36%) | called by muse, mutect2, varscan2
- ALDH1L1 | c.128-847T>G | Intron (SNP) | VAF 76/445 reads (17%) | called by muse, mutect2, varscan2
- ANXA2P2 | n.990G>A | RNA (SNP) | VAF 126/340 reads (37%) | catalogued as rs1342030810; called by muse, mutect2, varscan2
- AP000943.2 | chr11:94740960 G>T | 5'Flank (SNP) | VAF 93/412 reads (23%) | called by muse, mutect2, varscan2
- APOB | c.2436+81C>A | Intron (SNP) | VAF 60/299 reads (20%) | called by muse, mutect2, varscan2
- ARHGAP31 | c.-21C>A | 5'UTR (SNP) | VAF 100/511 reads (20%) | called by muse, varscan2
- C2CD5 | c.801-1074G>T | Intron (SNP) | VAF 62/236 reads (26%) | called by muse, mutect2, varscan2
- CCDC33 | c.1938+376G>T | Intron (SNP) | VAF 94/364 reads (26%) | called by muse, mutect2, varscan2
- CCDC33 | chr15:74336249 C>T | 3'Flank (SNP) | VAF 17/43 reads (40%) | catalogued as rs868205434; called by muse, mutect2, varscan2
- CD8A | c.*905C>T | 3'UTR (SNP) | VAF 78/301 reads (26%) | called by muse, mutect2, varscan2
- CEACAM18 | c.-19G>T | 5'UTR (SNP) | VAF 64/101 reads (63%) | called by muse, mutect2, varscan2
- CLK2P1 | n.877T>A | RNA (SNP) | VAF 191/747 reads (26%) | called by muse, mutect2, varscan2
- CMA1 | chr14:24501713 G>T | 3'Flank (SNP) | VAF 71/243 reads (29%) | called by muse, mutect2, varscan2
- CMA1 | chr14:24501714 G>T | 3'Flank (SNP) | VAF 69/238 reads (29%) | called by muse, mutect2, varscan2
- DDR2 | c.1504+83A>G | Intron (SNP) | VAF 96/371 reads (26%) | called by muse, mutect2, varscan2
- DYNC1H1 | c.12276-21A>T | Intron (SNP) | VAF 246/870 reads (28%) | called by muse, mutect2, varscan2
- EPHA8 | c.1315+124C>A | Intron (SNP) | VAF 40/178 reads (22%) | called by muse, mutect2, varscan2
- EYS | c.1767-6844G>T | Intron (SNP) | VAF 79/535 reads (15%) | called by muse, mutect2, varscan2
- EYS | c.1767-6845G>T | Intron (SNP) | VAF 81/539 reads (15%) | called by muse, mutect2, varscan2
- FAM169B | n.511C>G | RNA (SNP) | VAF 53/211 reads (25%) | called by muse, mutect2, varscan2
- FAM78B | c.*491G>T | 3'UTR (SNP) | VAF 93/383 reads (24%) | catalogued as rs908890499; called by muse, mutect2, varscan2
- GALC | chr14:87993430 G>T | 5'Flank (SNP) | VAF 121/520 reads (23%) | called by muse, mutect2, varscan2
- HBE1 | c.-267+36835C>T | Intron (SNP) | VAF 47/264 reads (18%) | catalogued as rs1353350997; called by muse, mutect2, varscan2
- HERC2P3 | chr15:20457644 T>A | 5'Flank (SNP) | VAF 44/328 reads (13%) | called by muse, mutect2, varscan2
- HPRT1 | c.-26C>A | 5'UTR (SNP) | VAF 207/563 reads (37%) | catalogued as COSV53778583; called by muse, mutect2, varscan2
- HSPA7 | n.339C>A | RNA (SNP) | VAF 122/803 reads (15%) | called by muse, mutect2, varscan2
- IARS1 | c.3283+199C>G | Intron (SNP) | VAF 40/128 reads (31%) | catalogued as rs1298476647; called by muse, mutect2, varscan2
- IL16 | c.3805+11T>A | Intron (SNP) | VAF 183/675 reads (27%) | called by muse, mutect2, varscan2
- KIF5C | c.292-2209C>A | Intron (SNP) | VAF 13/62 reads (21%) | called by muse, mutect2, varscan2
- LINC01205 | n.160G>T | RNA (SNP) | VAF 54/259 reads (21%) | called by muse, mutect2, varscan2
- LINC02860 | n.1021C>A | RNA (SNP) | VAF 92/343 reads (27%) | called by muse, mutect2, varscan2
- LNP1 | c.157-17del | Intron (DEL) | VAF 13/110 reads (12%) | catalogued as COSV101051188; called by mutect2, pindel, varscan2
- LNX1 | c.*1401A>C | 3'UTR (SNP) | VAF 26/173 reads (15%) | called by muse, mutect2
- MDS2 | chr1:23626787 T>A | 5'Flank (SNP) | VAF 5/17 reads (29%) | called by muse, mutect2, varscan2
- MDS2 | n.64A>G | RNA (SNP) | VAF 114/457 reads (25%) | called by muse, varscan2
- MIR1197 | n.38_39del | RNA (DEL) | VAF 47/209 reads (22%) | called by pindel, varscan2
- MIR299 | n.19C>T | RNA (SNP) | VAF 33/133 reads (25%) | called by muse, mutect2, varscan2
- MT1X | c.94+17C>T | Intron (SNP) | VAF 96/376 reads (26%) | catalogued as COSV101094145; called by muse, mutect2, varscan2
- MUC19 | chr12:40543807 G>T | 3'Flank (SNP) | VAF 11/66 reads (17%) | called by muse, mutect2, varscan2
- MYL2 | c.*29C>T | 3'UTR (SNP) | VAF 121/482 reads (25%) | catalogued as rs371503244; called by muse, mutect2, varscan2
- NACA | c.70+4478C>A | Intron (SNP) | VAF 86/392 reads (22%) | called by muse, mutect2, varscan2
- NARF | c.521-162G>T | Intron (SNP) | VAF 88/242 reads (36%) | called by muse, mutect2, varscan2
- NOC2LP2 | n.513G>T | RNA (SNP) | VAF 210/824 reads (25%) | called by muse, mutect2
- OSBPL7 | c.1120-35C>A | Intron (SNP) | VAF 52/134 reads (39%) | called by muse, mutect2, varscan2
- PCDHB6 | chr5:141157640 C>G | 3'Flank (SNP) | VAF 386/1036 reads (37%) | catalogued as rs782631491; called by muse, mutect2, varscan2
- PON3 | c.695+35C>A | Intron (SNP) | VAF 60/190 reads (32%) | called by muse, mutect2, varscan2
- PRR14 | c.192+334C>T | Intron (SNP) | VAF 58/299 reads (19%) | catalogued as rs777527795; called by muse, mutect2, varscan2
- REG1A | c.183+28del | Intron (DEL) | VAF 94/420 reads (22%) | called by mutect2, pindel, varscan2
- RGSL1 | c.301+584C>T | Intron (SNP) | VAF 57/223 reads (26%) | called by muse, mutect2, varscan2
- RNF217-AS1 | n.1768A>T | RNA (SNP) | VAF 32/157 reads (20%) | called by muse, mutect2, varscan2
- SAMHD1 | c.-45C>T | 5'UTR (SNP) | VAF 157/560 reads (28%) | catalogued as rs374493682, COSV99484353; called by muse, mutect2, varscan2
- SASH1 | c.386+24G>T | Intron (SNP) | VAF 48/176 reads (27%) | called by muse, mutect2, varscan2
- SCUBE1 | c.727+2707C>T | Intron (SNP) | VAF 130/467 reads (28%) | catalogued as rs764244254, COSV99298173; called by muse, mutect2, varscan2
- SFI1 | c.3069-91C>A | Intron (SNP) | VAF 72/230 reads (31%) | called by muse, mutect2, varscan2
- SIRT2 | c.1015-45A>C | Intron (SNP) | VAF 209/461 reads (45%) | called by muse, mutect2, varscan2
- SLC22A17 | n.1088G>A | RNA (SNP) | VAF 147/576 reads (26%) | called by muse, mutect2, varscan2
- SLC44A3 | c.278+1253C>T | Intron (SNP) | VAF 70/284 reads (25%) | catalogued as rs1276006019; called by muse, mutect2, varscan2
- SNRPN | chr15:24979975 C>A | 3'Flank (SNP) | VAF 19/75 reads (25%) | called by muse, mutect2
- SPANXB1 | c.-27G>T | 5'UTR (SNP) | VAF 159/1204 reads (13%) | called by muse, varscan2
- SPATA31C2 | n.2830G>T | RNA (SNP) | VAF 214/872 reads (25%) | called by muse, mutect2, varscan2
- SSX6P | n.70G>A | RNA (SNP) | VAF 62/341 reads (18%) | catalogued as rs781900449; called by muse, mutect2, varscan2
- SYN1 | c.*33C>A | 3'UTR (SNP) | VAF 62/241 reads (26%) | called by muse, mutect2, varscan2
- TCF7 | c.441+7681C>T | Intron (SNP) | VAF 103/260 reads (40%) | catalogued as rs1193455616; called by muse, mutect2, varscan2
- TG | c.7239+17693G>T | Intron (SNP) | VAF 22/84 reads (26%) | called by muse, mutect2
- TMEM269 | c.-14G>C | 5'UTR (SNP) | VAF 66/260 reads (25%) | called by muse, mutect2, varscan2
- TNK2 | c.-18-6760del | Intron (DEL) | VAF 17/164 reads (10%) | called by mutect2, pindel, varscan2
- TRDV2 | chr14:22418457 del CC | 5'Flank (DEL) | VAF 54/314 reads (17%) | called by mutect2, pindel, varscan2
- TTC16 | c.1764+32C>T | Intron (SNP) | VAF 34/81 reads (42%) | called by muse, mutect2, varscan2
- TTYH1 | c.126+1161G>T | Intron (SNP) | VAF 459/716 reads (64%) | called by muse, mutect2, varscan2
- TUBB7P | n.110A>C | RNA (SNP) | VAF 110/366 reads (30%) | called by muse, mutect2, varscan2
- ZBTB25 | c.*6607G>T | 3'UTR (SNP) | VAF 15/57 reads (26%) | called by muse, mutect2, varscan2
- ZMAT4 | c.103-18963G>T | Intron (SNP) | VAF 48/134 reads (36%) | called by muse, mutect2, varscan2
- ZNF185 | c.1209-3525G>T | Intron (SNP) | VAF 115/315 reads (37%) | called by muse, mutect2, varscan2
- ZNF559 | chr19:9324160 G>T | 5'Flank (SNP) | VAF 71/352 reads (20%) | called by muse, mutect2, varscan2
- ZNF99 | c.*761C>A | 3'UTR (SNP) | VAF 75/240 reads (31%) | called by muse, varscan2
